Somatic mutation profile of tumor specimen ALCH-B3ZA-TTP1-A (aliquot ALCH-B3ZA-TTP1-A-1-0-D-A80D-36) from ALCHEMIST case ALCH-B3ZA, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Large cell carcinoma, NOS; Age at diagnosis: 67.1 years (24,512 days).
Specimen ALCH-B3ZA-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e0371374-537c-46a0-89ad-312d3b82c7fa.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B3ZA-NB1-A (Blood Derived Normal), aliquot ALCH-B3ZA-NB1-A-1-0-D-A80D-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4465823d-fce0-42eb-97dd-61d10630a614

The open-access MAF lists 1,513 somatic variants for this specimen: 987 protein-altering or splice-affecting, 321 silent, 205 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 828, Silent 321, Intron 104, Nonsense Mutation 69, RNA 35, Frame Shift Del 34, Splice Site 29, 3'UTR 23, 5'UTR 21, 5'Flank 16, Splice Region 13, Frame Shift Ins 11.

Variants (750 of 1,513; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- HERC2 | c.9710T>A p.L3237* | Nonsense Mutation (SNP) | VAF 145/322 reads (45%) | catalogued as rs1555415658; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.844C>T p.R282W | Missense Mutation (SNP) | VAF 402/882 reads (46%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs28934574, CM056413, CM920678, COSV52662048, COSV52662222, COSV52701296; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ABCA6 | c.2026G>T p.A676S | Missense Mutation (SNP) | VAF 58/406 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1369483651, COSV99445769; called by muse, mutect2, varscan2
- ABCG2 | c.489G>T p.R163S | Missense Mutation (SNP) | VAF 84/486 reads (17%) | SIFT tolerated (0.07); PolyPhen benign (0.103); catalogued as COSV52948546; called by muse, mutect2, varscan2
- ACSF2 | c.67G>T p.A23S | Missense Mutation (SNP) | VAF 8/78 reads (10%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.037); catalogued as COSV55953977; called by muse, mutect2
- ACSL4 | c.826A>T p.M276L (on ENST00000340800 / NM_022977.2; = p.M235L on NM_004458.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 263/653 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs769723219; called by muse, mutect2, varscan2
- ACSM5 | c.65C>A p.S22Y | Missense Mutation (SNP) | VAF 286/902 reads (32%) | SIFT tolerated (1); PolyPhen benign (0.176); catalogued as COSV100089325, COSV59370986; called by muse, mutect2, varscan2
- ACSM5 | c.600G>T p.W200C | Missense Mutation (SNP) | VAF 156/786 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1204053040, COSV59370429; called by muse, mutect2, varscan2
- ADAMTS7 | c.2758G>A p.E920K | Missense Mutation (SNP) | VAF 176/369 reads (48%) | SIFT tolerated (0.27); PolyPhen benign (0.284); catalogued as rs753276180; called by muse, mutect2, varscan2
- AGT | c.1104G>A p.W368* | Nonsense Mutation (SNP) | VAF 172/411 reads (42%) | catalogued as rs868602913; called by muse, mutect2, varscan2
- AK5 | c.94G>T p.E32* (on ENST00000354567 / NM_174858.3; = p.E6* on NM_012093.4) | Nonsense Mutation (SNP) | VAF 65/188 reads (35%) | catalogued as COSV100481558; called by muse, mutect2, varscan2
- AKAP17A | c.511G>A p.E171K | Missense Mutation (SNP) | VAF 3/26 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs776400582; called by muse, mutect2
- ALDH1L1 | c.1472+5G>A | Splice Region (SNP) | VAF 60/359 reads (17%) | catalogued as rs775400311; called by muse, mutect2, varscan2
- ANGPT1 | c.473G>A p.R158Q | Missense Mutation (SNP) | VAF 21/293 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.84); catalogued as COSV52439970; called by muse, mutect2
- ANK2 | c.694-1G>A p.X232_splice | Splice Site (SNP) | VAF 141/920 reads (15%) | catalogued as rs1057523605; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ANKRD26 | c.1015C>A p.Q339K | Missense Mutation (SNP) | VAF 117/754 reads (16%) | SIFT tolerated (0.95); PolyPhen benign (0.006); catalogued as COSV65795793; called by muse, mutect2, varscan2
- ANXA10 | c.289G>T p.E97* | Nonsense Mutation (SNP) | VAF 89/599 reads (15%) | catalogued as COSV63739717; called by muse, mutect2, varscan2
- AP3B1 | c.2381C>A p.S794Y | Missense Mutation (SNP) | VAF 40/236 reads (17%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.034); catalogued as rs1190566826, COSV54892549; called by muse, mutect2, varscan2
- APBA1 | c.845G>T p.S282I | Missense Mutation (SNP) | VAF 121/248 reads (49%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.296); catalogued as COSV55231195; called by muse, mutect2, varscan2
- ARHGEF6 | c.213T>A p.N71K | Missense Mutation (SNP) | VAF 472/845 reads (56%) | SIFT tolerated, low confidence (0.96); PolyPhen benign (0); catalogued as rs776559762; called by muse, mutect2, varscan2
- ATN1 | c.2352C>A p.F784L | Missense Mutation (SNP) | VAF 36/584 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as rs1418627045, COSV100755921, COSV63112947; called by muse, mutect2
- BAIAP2L2 | c.76G>A p.A26T | Missense Mutation (SNP) | VAF 172/356 reads (48%) | SIFT deleterious (0.03); PolyPhen benign (0.296); catalogued as rs552550954, COSV59272746; called by muse, mutect2, varscan2
- BAIAP3 | c.335G>T p.R112L | Missense Mutation (SNP) | VAF 49/344 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.048); catalogued as rs767584126, COSV100181468; called by muse, mutect2, varscan2
- BAZ2B | c.2785G>T p.E929* | Nonsense Mutation (SNP) | VAF 105/434 reads (24%) | catalogued as COSV99680924; called by muse, mutect2, varscan2
- C10orf67 | c.1394G>A p.R465H | Missense Mutation (SNP) | VAF 14/74 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.931); catalogued as rs559972778; called by muse, mutect2, varscan2
- C16orf70 | c.1230del p.R411Gfs*6 | Frame Shift Del (DEL) | VAF 81/308 reads (26%) | catalogued as rs539297455, COSV54625370; called by mutect2, varscan2
- C1R | c.577G>A p.G193S (on ENST00000536053 / NM_001354346.2; = p.G179S on NM_001733.7) | Missense Mutation (SNP) | VAF 286/568 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56925144; called by muse, mutect2, varscan2
- C1orf94 | c.1333C>A p.P445T (on ENST00000488417 / NM_001134734.2; = p.P255T on NM_032884.5) | Missense Mutation (SNP) | VAF 78/607 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV64914246; called by muse, mutect2, varscan2
- C4orf51 | c.478C>T p.R160* | Nonsense Mutation (SNP) | VAF 72/519 reads (14%) | catalogued as rs778266384, COSV71264389; called by muse, mutect2, varscan2
- CAMK4 | c.16G>T p.V6L | Missense Mutation (SNP) | VAF 192/644 reads (30%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0); catalogued as rs748901600; called by muse, varscan2
- CAST | c.647C>T p.T216I (on ENST00000341926; = p.T299I on NM_001750.7 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 45/477 reads (9%) | SIFT tolerated (0.22); PolyPhen benign (0.384); catalogued as rs1373044275; called by muse, mutect2
- CBLC | c.1133G>T p.W378L | Missense Mutation (SNP) | VAF 11/61 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54321884; called by muse, mutect2, varscan2
- CCN5 | c.265G>T p.A89S | Missense Mutation (SNP) | VAF 51/258 reads (20%) | SIFT tolerated (0.37); PolyPhen benign (0.003); catalogued as rs772635492; called by muse, mutect2, varscan2
- CCT2 | c.436G>T p.V146F | Missense Mutation (SNP) | VAF 280/746 reads (38%) | SIFT tolerated (0.7); PolyPhen benign (0.012); catalogued as rs1218027325; called by muse, mutect2, varscan2
- CCZ1B | c.475G>A p.G159R | Missense Mutation (SNP) | VAF 61/381 reads (16%) | SIFT tolerated (0.25); PolyPhen benign (0.095); catalogued as rs748870315; called by muse, mutect2, varscan2
- CDCP2 | c.1297G>A p.G433S | Missense Mutation (SNP) | VAF 35/271 reads (13%) | SIFT tolerated, low confidence (0.57); PolyPhen benign (0); catalogued as rs747338763, COSV61283125; called by muse, mutect2, varscan2
- CDH10 | c.2081C>A p.T694K | Missense Mutation (SNP) | VAF 336/1394 reads (24%) | SIFT tolerated (0.1); PolyPhen benign (0.347); catalogued as COSV100051806, COSV52594816; called by muse, mutect2, varscan2
- CDH20 | c.1660C>G p.R554G | Missense Mutation (SNP) | VAF 32/153 reads (21%) | SIFT tolerated (0.74); PolyPhen benign (0.175); catalogued as rs776559067; called by muse, mutect2, varscan2
- CDKAL1 | c.40G>A p.E14K | Missense Mutation (SNP) | VAF 43/257 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV51187004; called by muse, mutect2, varscan2
- CDKN2A | c.104G>T p.G35V | Missense Mutation (SNP) | VAF 168/331 reads (51%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs746834149, CM065062, CM091775, CM950226, COSV58690447, COSV58690595, COSV58726978; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CERS2 | c.984C>G p.H328Q | Missense Mutation (SNP) | VAF 22/706 reads (3%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as rs1298589032; called by muse, mutect2
- CFH | c.1064A>G p.Y355C | Missense Mutation (SNP) | VAF 160/823 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM111064, CM156567; called by muse, mutect2, varscan2
- CHRNA4 | c.1661C>T p.P554L | Missense Mutation (SNP) | VAF 40/192 reads (21%) | SIFT tolerated (0.36); PolyPhen benign (0.005); catalogued as rs56000199; ClinVar: likely benign; called by muse, mutect2, varscan2
- CLCN3 | c.1429G>T p.D477Y | Missense Mutation (SNP) | VAF 59/381 reads (15%) | SIFT tolerated (0.9); PolyPhen benign (0.285); catalogued as rs1177334780; called by muse, mutect2, varscan2
- CLCNKA | c.1298G>T p.G433V | Missense Mutation (SNP) | VAF 98/584 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58891019, COSV58892408; called by muse, mutect2, varscan2
- CLTCL1 | c.812G>A p.G271D | Missense Mutation (SNP) | VAF 81/186 reads (44%) | SIFT tolerated (0.23); PolyPhen benign (0.014); catalogued as rs782220211; called by muse, mutect2, varscan2
- CNGA2 | c.943C>A p.P315T | Missense Mutation (SNP) | VAF 115/205 reads (56%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.921); catalogued as COSV100323996; called by muse, mutect2, varscan2
- CNTN1 | c.1951G>T p.D651Y | Missense Mutation (SNP) | VAF 51/376 reads (14%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.908); catalogued as COSV100751617; called by muse, mutect2, varscan2
- COL20A1 | c.1406C>T p.P469L | Missense Mutation (SNP) | VAF 26/164 reads (16%) | SIFT tolerated (0.19); PolyPhen benign (0.349); catalogued as rs202110157; called by muse, mutect2, varscan2
- COL22A1 | c.1978-1G>T p.X660_splice | Splice Site (SNP) | VAF 109/337 reads (32%) | catalogued as COSV57337363; called by muse, mutect2, varscan2
- COL5A2 | c.248C>T p.A83V | Missense Mutation (SNP) | VAF 435/1178 reads (37%) | SIFT tolerated (0.1); PolyPhen benign (0.007); catalogued as rs866611080, COSV66413986; called by muse, mutect2, varscan2
- COPS7B | c.589C>T p.Q197* | Nonsense Mutation (SNP) | VAF 184/774 reads (24%) | catalogued as COSV100602245; called by muse, mutect2, varscan2
- COX16 | c.274C>G p.L92V | Missense Mutation (SNP) | VAF 75/426 reads (18%) | SIFT tolerated (0.28); PolyPhen benign (0.024); catalogued as COSV101112181; called by muse, mutect2, varscan2
- CPA2 | c.202C>T p.R68* | Nonsense Mutation (SNP) | VAF 83/859 reads (10%) | catalogued as rs138468930; called by muse, mutect2
- CSMD2 | c.9188del p.P3063Lfs*62 | Frame Shift Del (DEL) | VAF 37/262 reads (14%) | catalogued as COSV99592993; called by mutect2, pindel, varscan2
- CSMD3 | c.5395+1del p.X1799_splice (on ENST00000297405 / NM_001363185.1; = p.X1695_splice on NM_052900.3) | Splice Site (DEL) | VAF 120/431 reads (28%) | catalogued as COSV99830115; called by mutect2, pindel, varscan2
- CYP4F3 | c.1064G>A p.R355Q | Missense Mutation (SNP) | VAF 28/164 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.867); catalogued as rs141822395, COSV99658711; called by muse, mutect2, varscan2
- DAAM2 | c.264G>T p.Q88H | Missense Mutation (SNP) | VAF 50/460 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.011); catalogued as rs1562035568; called by muse, mutect2, varscan2
- DAO | c.194C>T p.A65V | Missense Mutation (SNP) | VAF 31/184 reads (17%) | SIFT tolerated (0.21); PolyPhen benign (0.001); catalogued as rs750347943, COSV57322660; called by muse, mutect2, varscan2
- DAOA | c.198G>T p.E66D | Missense Mutation (SNP) | VAF 146/653 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.161); catalogued as rs201206506, COSV100298612; called by muse, mutect2, varscan2
- DCDC2C | c.182G>A p.R61H | Missense Mutation (SNP) | VAF 59/127 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1218150888; called by muse, mutect2, varscan2
- DGKK | c.1318G>T p.D440Y | Missense Mutation (SNP) | VAF 232/539 reads (43%) | SIFT tolerated (0.38); PolyPhen benign (0.123); catalogued as COSV65707580; called by muse, mutect2, varscan2
- DIAPH3 | c.3320A>T p.E1107V | Missense Mutation (SNP) | VAF 271/501 reads (54%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.328); catalogued as rs774618164; called by muse, mutect2, varscan2
- DMD | c.6586T>C p.C2196R | Missense Mutation (SNP) | VAF 164/936 reads (18%) | SIFT tolerated (0.13); PolyPhen benign (0.038); catalogued as rs794727677; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DNAH1 | c.436C>T p.Q146* | Nonsense Mutation (SNP) | VAF 106/207 reads (51%) | catalogued as rs747954653; called by muse, mutect2, varscan2
- DNAH11 | c.1505del p.G502Dfs*6 | Frame Shift Del (DEL) | VAF 58/320 reads (18%) | catalogued as COSV104409949; called by mutect2, pindel, varscan2
- DNAH14 | c.487G>T p.E163* | Nonsense Mutation (SNP) | VAF 45/156 reads (29%) | catalogued as rs573399214; called by muse, mutect2, varscan2
- DNAH17 | c.9998C>A p.S3333* | Nonsense Mutation (SNP) | VAF 59/214 reads (28%) | catalogued as COSV67751811; called by muse, mutect2, varscan2
- DNAH9 | c.6311C>A p.P2104H | Missense Mutation (SNP) | VAF 191/414 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV99303878; called by muse, mutect2, varscan2
- DNAH9 | c.8593G>T p.A2865S | Missense Mutation (SNP) | VAF 47/130 reads (36%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.609); catalogued as COSV52350502; called by muse, mutect2, varscan2
- DPP6 | c.927T>A p.D309E (on ENST00000377770 / NM_001364500.2; = p.D247E on NM_001936.5) | Missense Mutation (SNP) | VAF 120/486 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.315); catalogued as COSV59600786; called by muse, mutect2, varscan2
- DRAXIN | c.175C>G p.R59G | Missense Mutation (SNP) | VAF 80/226 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV53844518; called by muse, mutect2, varscan2
- DSC2 | c.449del p.G150Vfs*24 | Frame Shift Del (DEL) | VAF 174/1139 reads (15%) | catalogued as CM107152; called by mutect2, pindel, varscan2
- DSCAM | c.3089G>T p.G1030V | Missense Mutation (SNP) | VAF 189/851 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.566); catalogued as COSV68033737; called by muse, mutect2, varscan2
- DSG1 | c.2660G>A p.R887Q | Missense Mutation (SNP) | VAF 93/524 reads (18%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.563); catalogued as rs368044134; called by muse, mutect2, varscan2
- EFHC2 | c.352C>A p.P118T | Missense Mutation (SNP) | VAF 74/189 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs745634963; called by muse, mutect2, varscan2
- EIF4G1 | c.1088G>T p.G363V (on ENST00000346169 / NM_198241.3; = p.G167V on NM_004953.5) | Missense Mutation (SNP) | VAF 9/33 reads (27%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.996); catalogued as COSV59992423; called by muse, mutect2, varscan2
- EMCN | c.387G>C p.Q129H | Missense Mutation (SNP) | VAF 25/227 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs758396394; called by muse, varscan2
- EPB41L3 | c.2225T>C p.F742S | Missense Mutation (SNP) | VAF 165/629 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1454793235; called by muse, mutect2, varscan2
- EVX2 | c.709C>T p.Q237* | Nonsense Mutation (SNP) | VAF 43/200 reads (22%) | catalogued as rs1296906491; called by muse, mutect2, varscan2
- EXPH5 | c.5934C>G p.Y1978* | Nonsense Mutation (SNP) | VAF 28/75 reads (37%) | catalogued as COSV104380371, COSV56208559; called by muse, varscan2
- FAT2 | c.9599C>A p.T3200K | Missense Mutation (SNP) | VAF 234/755 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.846); catalogued as COSV55822841; called by muse, mutect2, varscan2
- FAT4 | c.12499G>C p.A4167P | Missense Mutation (SNP) | VAF 65/291 reads (22%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.53); catalogued as COSV58706154; called by muse, mutect2, varscan2
- FBN2 | c.6475C>T p.H2159Y | Missense Mutation (SNP) | VAF 52/494 reads (11%) | SIFT tolerated (0.37); PolyPhen benign (0.201); catalogued as COSV52504559; called by muse, mutect2, varscan2
- FCRL6 | c.44G>T p.G15V | Missense Mutation (SNP) | VAF 250/538 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.577); catalogued as rs772715372, COSV100220075, COSV58942056; called by muse, mutect2, varscan2
- FEZF2 | c.718G>T p.A240S | Missense Mutation (SNP) | VAF 108/258 reads (42%) | SIFT tolerated (0.3); PolyPhen benign (0.011); catalogued as COSV51864819; called by muse, mutect2, varscan2
- FFAR3 | c.854C>A p.A285D | Missense Mutation (SNP) | VAF 156/888 reads (18%) | SIFT tolerated (0.23); PolyPhen benign (0.156); catalogued as rs760421845; called by mutect2, varscan2
- FGD5 | c.3052G>C p.V1018L | Missense Mutation (SNP) | VAF 75/163 reads (46%) | SIFT tolerated (0.07); PolyPhen benign (0.019); catalogued as rs777806990; called by muse, mutect2, varscan2
- FGF3 | c.188G>C p.R63P | Missense Mutation (SNP) | VAF 95/513 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.815); catalogued as COSV61925190; called by muse, mutect2, varscan2
- FGG | c.973C>A p.P325T | Missense Mutation (SNP) | VAF 50/349 reads (14%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.758); catalogued as COSV60195612; called by muse, mutect2, varscan2
- FIGLA | c.410A>G p.Y137C | Missense Mutation (SNP) | VAF 66/360 reads (18%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.751); catalogued as rs781854674; called by muse, mutect2
- FLG | c.6431C>A p.P2144Q | Missense Mutation (SNP) | VAF 148/2385 reads (6%) | SIFT deleterious (0.04); PolyPhen benign (0.014); catalogued as rs769538852; called by muse, mutect2
- FLG | c.3269G>T p.G1090V | Missense Mutation (SNP) | VAF 1639/2110 reads (78%) | SIFT deleterious (0.03); PolyPhen benign (0.187); catalogued as COSV64252176; called by mutect2, varscan2
- FLG | c.2987G>A p.G996E | Missense Mutation (SNP) | VAF 1494/2028 reads (74%) | SIFT deleterious (0.01); PolyPhen benign (0.28); catalogued as rs561298363; called by muse, varscan2
- FLRT1 | c.505G>A p.E169K | Missense Mutation (SNP) | VAF 124/326 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1210608976; called by muse, mutect2, varscan2
- FOXC2 | c.354C>A p.N118K | Missense Mutation (SNP) | VAF 168/787 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM1312284, COSV57444138; called by muse, mutect2, varscan2
- FSCB | c.902C>A p.P301H | Missense Mutation (SNP) | VAF 72/219 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.106); catalogued as COSV61219034; called by muse, mutect2, varscan2
- G6PC | c.133G>C p.V45L | Missense Mutation (SNP) | VAF 156/900 reads (17%) | SIFT tolerated (0.11); PolyPhen benign (0.067); catalogued as rs145749644, COSV53831075; called by muse, mutect2, varscan2
- GABRD | c.1343C>T p.A448V | Missense Mutation (SNP) | VAF 12/41 reads (29%) | SIFT tolerated (0.65); PolyPhen benign (0); catalogued as rs756592609, COSV66080483; called by muse, mutect2, varscan2
- GEMIN4 | c.1528G>T p.G510C | Missense Mutation (SNP) | VAF 122/279 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100021363; called by muse, mutect2, varscan2
- GGA2 | c.1526C>T p.P509L | Missense Mutation (SNP) | VAF 52/254 reads (20%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.868); catalogued as COSV59170573; called by muse, mutect2, varscan2
- GOT1L1 | c.866C>A p.P289H | Missense Mutation (SNP) | VAF 40/147 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV56876483; called by muse, mutect2, varscan2
- GPR149 | c.664C>A p.P222T | Missense Mutation (SNP) | VAF 147/379 reads (39%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.864); catalogued as rs750467435; called by muse, mutect2, varscan2
- GPR42 | c.854C>A p.A285D | Missense Mutation (SNP) | VAF 9/81 reads (11%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.446); catalogued as rs762627493; called by mutect2, varscan2
- GRAMD1B | c.1488C>G p.L496= | Splice Region (SNP) | VAF 108/234 reads (46%) | catalogued as COSV59203394; called by muse, mutect2, varscan2
- GRIN2B | c.1310A>G p.Q437R | Missense Mutation (SNP) | VAF 510/1018 reads (50%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV74206723; called by muse, mutect2, varscan2
- H2AC13 | c.377A>T p.K126M | Missense Mutation (SNP) | VAF 46/374 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.318); catalogued as COSV62440789; called by muse, mutect2, varscan2
- H2BC14 | c.355G>T p.V119F | Missense Mutation (SNP) | VAF 54/647 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.789); catalogued as COSV60797715; called by muse, mutect2
- HDAC8 | c.970G>T p.G324W | Missense Mutation (SNP) | VAF 139/388 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV101005269, COSV101005328; called by muse, mutect2, varscan2
- HIPK4 | c.673C>T p.R225C | Missense Mutation (SNP) | VAF 142/446 reads (32%) | SIFT deleterious (0.04); PolyPhen benign (0.403); catalogued as rs752564037, COSV52520308; called by muse, mutect2, varscan2
- HLA-DMB | c.721C>T p.R241W | Missense Mutation (SNP) | VAF 131/777 reads (17%) | SIFT tolerated (0.16); PolyPhen benign (0.067); catalogued as rs1164573532, COSV101186855; called by muse, mutect2, varscan2
- HR | c.320C>A p.P107Q | Missense Mutation (SNP) | VAF 114/462 reads (25%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0.138); catalogued as rs141011340; called by muse, mutect2, varscan2
- HRC | c.559G>A p.G187R | Missense Mutation (SNP) | VAF 85/229 reads (37%) | SIFT tolerated (0.23); PolyPhen benign (0.166); catalogued as rs1234670476; called by muse, varscan2
- HRNR | c.932G>C p.R311P | Missense Mutation (SNP) | VAF 116/2028 reads (6%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.549); catalogued as COSV64263761; called by muse, mutect2
- IGHV1-24 | c.130T>A p.S44T | Missense Mutation (SNP) | VAF 177/757 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.678); catalogued as rs781895821; called by muse, mutect2, varscan2
- IGHV3-43 | c.88G>C p.V30L | Missense Mutation (SNP) | VAF 48/274 reads (18%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.001); catalogued as rs188914311; called by muse, mutect2, varscan2
- INF2 | c.3605C>T p.S1202L | Missense Mutation (SNP) | VAF 12/41 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.255); catalogued as rs751351877; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ITGA5 | c.2207C>T p.P736L | Missense Mutation (SNP) | VAF 42/319 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99516626; called by muse, mutect2, varscan2
- ITGAX | c.1842G>C p.R614S | Missense Mutation (SNP) | VAF 58/180 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV99191453; called by muse, mutect2, varscan2
- JMJD6 | c.326C>G p.S109* | Nonsense Mutation (SNP) | VAF 160/666 reads (24%) | catalogued as COSV100373071; called by muse, mutect2, varscan2
- JPH1 | c.982G>C p.E328Q | Missense Mutation (SNP) | VAF 212/1299 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV60609692; called by muse, mutect2, varscan2
- KCNA2 | c.47C>A p.P16H | Missense Mutation (SNP) | VAF 75/175 reads (43%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.595); catalogued as COSV60370839; called by muse, mutect2, varscan2
- KCNB1 | c.160C>A p.R54S | Missense Mutation (SNP) | VAF 148/280 reads (53%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.627); catalogued as COSV100870472; called by muse, mutect2, varscan2
- KCNB2 | c.2652G>C p.K884N | Missense Mutation (SNP) | VAF 130/431 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.907); catalogued as COSV73050869; called by muse, varscan2
- KCNB2 | c.2722G>A p.E908K | Missense Mutation (SNP) | VAF 36/119 reads (30%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.48); catalogued as COSV101578879; called by muse, varscan2
- KIAA1522 | c.2597C>A p.A866D (on ENST00000373480 / NM_001198972.2; = p.A925D on NM_020888.3) | Missense Mutation (SNP) | VAF 54/118 reads (46%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.494); catalogued as rs1273897772; called by muse, mutect2, varscan2
- KIF2B | c.1685C>A p.P562Q | Missense Mutation (SNP) | VAF 48/682 reads (7%) | SIFT tolerated (0.08); PolyPhen benign (0.102); catalogued as COSV52134934; called by muse, mutect2
- KIR3DL3 | c.803C>G p.A268G | Missense Mutation (SNP) | VAF 210/650 reads (32%) | SIFT tolerated (0.68); PolyPhen benign (0.173); catalogued as COSV99400480; called by muse, mutect2, varscan2
- KLHL33 | c.1594G>T p.A532S | Missense Mutation (SNP) | VAF 20/119 reads (17%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.321); catalogued as rs982908797; called by muse, mutect2, varscan2
- KLK10 | c.409G>T p.D137Y | Missense Mutation (SNP) | VAF 93/287 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100011240; called by muse, mutect2, varscan2
- KLK4 | c.598A>C p.K200Q | Missense Mutation (SNP) | VAF 113/730 reads (15%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.53); catalogued as COSV60676471; called by muse, mutect2, varscan2
- KLK9 | c.569C>A p.A190E | Missense Mutation (SNP) | VAF 124/326 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51593093; called by muse, mutect2, varscan2
- KMT5A | c.238G>T p.E80* | Nonsense Mutation (SNP) | VAF 80/695 reads (12%) | catalogued as COSV57863736; called by muse, varscan2
- KRTAP19-1 | c.240C>A p.Y80* | Nonsense Mutation (SNP) | VAF 109/649 reads (17%) | catalogued as rs757510085; called by muse, mutect2, varscan2
- LAMA1 | c.5812G>T p.V1938F | Missense Mutation (SNP) | VAF 184/1199 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.007); catalogued as rs1461644318; called by muse, mutect2, varscan2
- LGALS9 | c.238G>C p.G80R | Missense Mutation (SNP) | VAF 210/618 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as COSV56351318; called by muse, mutect2, varscan2
- LGR4 | c.149C>T p.A50V | Missense Mutation (SNP) | VAF 35/198 reads (18%) | SIFT tolerated (0.1); PolyPhen benign (0.035); catalogued as rs1314637648; called by muse, mutect2, varscan2
- LIN7C | c.14G>T p.G5V | Missense Mutation (SNP) | VAF 95/600 reads (16%) | SIFT tolerated, low confidence (0.4); PolyPhen benign (0); catalogued as COSV53415175; called by muse, mutect2, varscan2
- LINGO2 | c.186G>T p.L62F | Missense Mutation (SNP) | VAF 21/82 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58058954; called by muse, mutect2, varscan2
- LMX1A | c.845G>T p.G282V | Missense Mutation (SNP) | VAF 16/90 reads (18%) | SIFT tolerated (0.29); PolyPhen benign (0.28); catalogued as COSV54221439; called by muse, varscan2
- LONRF3 | c.1533C>T p.C511= (on ENST00000371628 / NM_001031855.3; = p.C470= on NM_024778.5) | Splice Region (SNP) | VAF 56/129 reads (43%) | catalogued as rs1454862458; called by muse, mutect2, varscan2
- LOXHD1 | c.5865G>T p.W1955C (on ENST00000642948; = p.W1893C on NM_144612.7) | Missense Mutation (SNP) | VAF 48/179 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV56072606; called by muse, mutect2, varscan2
- LRP1 | c.779G>T p.R260L | Missense Mutation (SNP) | VAF 136/401 reads (34%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as rs757759198, COSV54510162; called by muse, mutect2, varscan2
- LRRC32 | c.487C>A p.R163S | Missense Mutation (SNP) | VAF 119/297 reads (40%) | SIFT tolerated (0.2); PolyPhen benign (0.298); catalogued as COSV52632602; called by muse, mutect2, varscan2
- LRRC56 | c.1166G>T p.R389M | Missense Mutation (SNP) | VAF 59/170 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.039); catalogued as COSV99530622; called by muse, mutect2, varscan2
- LY6K | c.98G>T p.R33L | Missense Mutation (SNP) | VAF 12/81 reads (15%) | SIFT tolerated (0.3); PolyPhen benign (0.021); catalogued as COSV52832631; called by muse, mutect2, varscan2
- MAGEC1 | c.2182C>T p.Q728* | Nonsense Mutation (SNP) | VAF 28/152 reads (18%) | catalogued as COSV53579853; called by muse, mutect2, varscan2
- MAP3K21 | c.2852G>T p.R951I | Missense Mutation (SNP) | VAF 114/593 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.548); catalogued as COSV64041338; called by muse, mutect2, varscan2
- MATN2 | c.2653C>A p.L885M | Missense Mutation (SNP) | VAF 45/202 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV54716930; called by muse, mutect2, varscan2
- MCL1 | c.750G>A p.M250I | Missense Mutation (SNP) | VAF 138/2289 reads (6%) | SIFT tolerated (0.07); PolyPhen benign (0.006); catalogued as COSV100329722; called by muse, mutect2
- MCMBP | c.638G>T p.G213V | Missense Mutation (SNP) | VAF 180/338 reads (53%) | SIFT tolerated (0.15); PolyPhen benign (0.039); catalogued as COSV100750143; called by muse, mutect2, varscan2
- MED12L | c.3307G>T p.V1103L | Missense Mutation (SNP) | VAF 41/290 reads (14%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.976); catalogued as COSV56380842; called by muse, mutect2, varscan2
- MEGF6 | c.1666C>T p.P556S | Missense Mutation (SNP) | VAF 29/153 reads (19%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.742); catalogued as rs780543966; called by muse, mutect2, varscan2
- MGAM | c.1942C>A p.L648I | Missense Mutation (SNP) | VAF 106/280 reads (38%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.547); catalogued as COSV72074603; called by muse, mutect2, varscan2
- MIB1 | c.2146C>T p.R716C | Missense Mutation (SNP) | VAF 114/590 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV55088269; called by muse, mutect2, varscan2
- MPDZ | c.3255A>T p.K1085N | Missense Mutation (SNP) | VAF 93/170 reads (55%) | SIFT tolerated (0.31); PolyPhen benign (0.003); catalogued as COSV59924365; called by muse, mutect2, varscan2
- MPPE1 | c.952G>A p.E318K | Missense Mutation (SNP) | VAF 69/573 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs755998099; called by muse, mutect2, varscan2
- MRPS9 | c.590G>C p.S197T | Missense Mutation (SNP) | VAF 28/306 reads (9%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.706); catalogued as COSV51521177; called by muse, mutect2
- MTX3 | c.926G>T p.R309L (on ENST00000512528 / NM_001363818.2; = p.R248L on NM_001167741.2) | Missense Mutation (SNP) | VAF 192/621 reads (31%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0); catalogued as rs767683973; called by muse, mutect2, varscan2
- MUC5AC | c.1800C>A p.F600L | Missense Mutation (SNP) | VAF 17/161 reads (11%) | SIFT deleterious (0.04); catalogued as COSV100650702; called by muse, mutect2, varscan2
- MYH13 | c.1957G>C p.A653P | Missense Mutation (SNP) | VAF 66/156 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.964); catalogued as rs1567666681; called by muse, mutect2, varscan2
- MYH2 | c.1326G>T p.M442I | Missense Mutation (SNP) | VAF 574/1328 reads (43%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.584); catalogued as COSV55443146; called by muse, mutect2, varscan2
- MYH8 | c.4210G>C p.E1404Q | Missense Mutation (SNP) | VAF 313/689 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV67961652; called by muse, mutect2, varscan2
- NAT8 | c.118C>G p.P40A | Missense Mutation (SNP) | VAF 29/96 reads (30%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.922); catalogued as COSV99722077; called by muse, mutect2, varscan2
- NCAPH2 | c.1785G>C p.Q595H | Missense Mutation (SNP) | VAF 24/85 reads (28%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.998); catalogued as rs1411611415; called by muse, mutect2, varscan2
- NEK1 | c.3745G>A p.D1249N | Missense Mutation (SNP) | VAF 14/123 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1343363234; called by muse, mutect2, varscan2
- NFRKB | c.2836C>T p.R946C (on ENST00000446488 / NM_001143835.2; = p.R971C on NM_006165.3) | Missense Mutation (SNP) | VAF 99/444 reads (22%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.981); catalogued as rs1299880854; called by muse, mutect2, varscan2
- NHS | c.713G>A p.R238H | Missense Mutation (SNP) | VAF 131/305 reads (43%) | SIFT tolerated (0.28); PolyPhen benign (0.02); catalogued as rs999129147, COSV66274865; called by muse, mutect2, varscan2
- NIPBL | c.4021A>G p.K1341E | Missense Mutation (SNP) | VAF 50/236 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.844); catalogued as rs1212163125; called by muse, mutect2, varscan2
- NLRC5 | c.2626G>A p.D876N | Missense Mutation (SNP) | VAF 77/350 reads (22%) | SIFT deleterious (0.04); PolyPhen benign (0.024); catalogued as rs1300512817; called by muse, mutect2, varscan2
- NLRP14 | c.2803del p.E935Nfs*2 | Frame Shift Del (DEL) | VAF 62/498 reads (12%) | catalogued as COSV55067005; called by mutect2, pindel, varscan2
- NLRP3 | c.289G>A p.A97T | Missense Mutation (SNP) | VAF 470/950 reads (49%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as rs1272621702; called by muse, mutect2, varscan2
- NLRP5 | c.1927G>A p.E643K | Missense Mutation (SNP) | VAF 75/251 reads (30%) | SIFT tolerated (1); PolyPhen benign (0.011); catalogued as rs1292298315, COSV66764392; called by muse, mutect2, varscan2
- NMS | c.230C>G p.T77S | Missense Mutation (SNP) | VAF 24/203 reads (12%) | SIFT tolerated (0.12); PolyPhen benign (0.005); catalogued as COSV65259221; called by muse, mutect2, varscan2
- NSD1 | c.1741G>C p.E581Q | Missense Mutation (SNP) | VAF 13/71 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.107); catalogued as COSV61786924; called by muse, mutect2, varscan2
- OBSL1 | c.4285G>T p.V1429L | Missense Mutation (SNP) | VAF 84/444 reads (19%) | SIFT tolerated (0.36); PolyPhen possibly damaging (0.841); catalogued as COSV99523010; called by muse, mutect2, varscan2
- OPA1 | c.2489G>T p.W830L (on ENST00000361510 / NM_130837.3; = p.W775L on NM_015560.3) | Missense Mutation (SNP) | VAF 183/654 reads (28%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.533); catalogued as rs1287548904; called by muse, mutect2, varscan2
- OR10X1 | c.762C>A p.F254L | Missense Mutation (SNP) | VAF 58/488 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV63767348; called by muse, mutect2, varscan2
- OR10Z1 | c.896C>A p.T299K | Missense Mutation (SNP) | VAF 203/381 reads (53%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as COSV63524134; called by muse, mutect2, varscan2
- OR1C1 | c.578C>T p.S193F | Missense Mutation (SNP) | VAF 435/785 reads (55%) | SIFT tolerated (0.71); PolyPhen benign (0.345); catalogued as COSV68715895; called by muse, mutect2, varscan2
- OR1J4 | c.235C>A p.P79T | Missense Mutation (SNP) | VAF 182/551 reads (33%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.931); catalogued as COSV61589735; called by muse, mutect2, varscan2
- OR2A42 | c.73C>A p.L25I | Missense Mutation (SNP) | VAF 18/63 reads (29%) | SIFT tolerated (0.06); PolyPhen benign (0.027); catalogued as COSV101195835; called by mutect2, varscan2
- OR2G2 | c.595G>T p.E199* | Nonsense Mutation (SNP) | VAF 357/709 reads (50%) | catalogued as COSV60739904; called by muse, mutect2, varscan2
- OR5D14 | c.337G>A p.E113K | Missense Mutation (SNP) | VAF 32/282 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.983); catalogued as COSV100162295; called by muse, mutect2, varscan2
- OR5D14 | c.515G>T p.G172V | Missense Mutation (SNP) | VAF 122/798 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.905); catalogued as COSV100162553; called by muse, mutect2, varscan2
- OR5D16 | c.854C>T p.P285L | Missense Mutation (SNP) | VAF 196/749 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1478355993; called by muse, mutect2, varscan2
- OR5D18 | c.824C>A p.A275D | Missense Mutation (SNP) | VAF 169/675 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.254); catalogued as COSV61736239; called by muse, mutect2, varscan2
- OR5K3 | c.775C>G p.R259G | Missense Mutation (SNP) | VAF 26/68 reads (38%) | SIFT deleterious (0.03); PolyPhen benign (0.124); catalogued as COSV67350503; called by muse, mutect2, varscan2
- OR5T1 | c.302dup p.N101Kfs*2 | Frame Shift Ins (INS) | VAF 72/252 reads (29%) | catalogued as rs780397839; called by mutect2, pindel, varscan2
- OR5T2 | c.352C>T p.P118S | Missense Mutation (SNP) | VAF 17/117 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.696); catalogued as COSV100507084; called by muse, varscan2
- OR8A1 | c.676G>C p.G226R | Missense Mutation (SNP) | VAF 72/434 reads (17%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV52509838; called by muse, mutect2, varscan2
- OR8B3 | c.692C>A p.T231N | Missense Mutation (SNP) | VAF 65/185 reads (35%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.072); catalogued as rs755246139; called by muse, mutect2, varscan2
- OR8K3 | c.591G>C p.L197F | Missense Mutation (SNP) | VAF 53/175 reads (30%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.072); catalogued as rs996597874, COSV57130899, COSV57132779; called by muse, mutect2, varscan2
- OXLD1 | c.60+4A>C | Splice Region (SNP) | VAF 25/430 reads (6%) | catalogued as rs1443045264; called by muse, mutect2
- PACRG | c.701C>T p.T234I | Missense Mutation (SNP) | VAF 51/122 reads (42%) | SIFT tolerated, low confidence (0.49); PolyPhen benign (0.117); catalogued as COSV61302152; called by muse, mutect2, varscan2
- PCDH17 | c.515C>A p.T172K | Missense Mutation (SNP) | VAF 423/714 reads (59%) | SIFT deleterious (0); PolyPhen benign (0.359); catalogued as rs781536747, COSV64973090; called by muse, mutect2, varscan2
- PCDH19 | c.3134G>T p.S1045I (on ENST00000373034 / NM_001184880.2; = p.S997I on NM_020766.3) | Missense Mutation (SNP) | VAF 181/533 reads (34%) | SIFT tolerated, low confidence (0.06); PolyPhen probably damaging (0.986); catalogued as COSV99718987; called by muse, mutect2, varscan2
- PCDHGB5 | c.1849C>A p.L617M | Missense Mutation (SNP) | VAF 87/499 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs759278103; called by muse, mutect2, varscan2
- PCDHGC3 | c.1373C>T p.S458F | Missense Mutation (SNP) | VAF 75/377 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.365); catalogued as rs1377364370; called by muse, mutect2, varscan2
- PCLO | c.14484G>T p.Q4828H | Missense Mutation (SNP) | VAF 180/787 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100437681; called by muse, mutect2, varscan2
- PDE3B | c.2147C>A p.P716H | Missense Mutation (SNP) | VAF 31/129 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56381183; called by muse, mutect2, varscan2
- PDE6A | c.1543G>C p.E515Q | Missense Mutation (SNP) | VAF 63/442 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.78); catalogued as COSV54926420; called by muse, mutect2, varscan2
- PIAS3 | c.904G>T p.A302S | Missense Mutation (SNP) | VAF 486/653 reads (74%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.601); catalogued as rs1553735080, COSV104427873; called by muse, mutect2, varscan2
- PIF1 | c.329C>T p.P110L | Missense Mutation (SNP) | VAF 22/41 reads (54%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); catalogued as rs1002140057; called by muse, mutect2, varscan2
- PIM3 | c.301G>A p.G101S | Missense Mutation (SNP) | VAF 96/211 reads (45%) | SIFT tolerated (0.52); PolyPhen benign (0.145); catalogued as rs1264745395; called by muse, mutect2, varscan2
- PIP5K1A | c.255G>T p.L85F (on ENST00000368888 / NM_001135638.2; = p.L72F on NM_003557.3) | Missense Mutation (SNP) | VAF 186/1878 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV62959938; called by muse, mutect2
- PKD1 | c.3409G>T p.V1137F | Missense Mutation (SNP) | VAF 236/637 reads (37%) | SIFT deleterious (0.05); PolyPhen benign (0.124); catalogued as rs375354209; called by muse, mutect2, varscan2
- PKD1L1 | c.3232C>G p.Q1078E | Missense Mutation (SNP) | VAF 73/552 reads (13%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.76); catalogued as COSV56958138; called by muse, mutect2, varscan2
- PLCG2 | c.3336C>G p.I1112M | Missense Mutation (SNP) | VAF 17/114 reads (15%) | SIFT tolerated (0.08); PolyPhen benign (0.144); catalogued as COSV63867910; called by muse, mutect2, varscan2
- PLCH1 | c.4609G>C p.E1537Q (on ENST00000340059 / NM_001130960.2; = p.E1529Q on NM_014996.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 73/444 reads (16%) | SIFT tolerated, low confidence (0.53); PolyPhen benign (0.01); catalogued as rs527988724; called by muse, mutect2, varscan2
- PLEKHA5 | c.836A>G p.K279R | Missense Mutation (SNP) | VAF 18/157 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.247); catalogued as rs760025022; called by muse, mutect2
- PLG | c.2125G>A p.G709S | Missense Mutation (SNP) | VAF 174/480 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1237479945; called by muse, mutect2, varscan2
- PLXNC1 | c.429C>A p.S143R | Missense Mutation (SNP) | VAF 6/31 reads (19%) | SIFT tolerated (0.13); PolyPhen benign (0.035); catalogued as COSV51577899; called by muse, mutect2, varscan2
- POTEF | c.388G>T p.E130* | Nonsense Mutation (SNP) | VAF 116/783 reads (15%) | catalogued as COSV62540797; called by muse, mutect2, varscan2
- POU4F1 | c.872C>T p.S291L | Missense Mutation (SNP) | VAF 310/472 reads (66%) | SIFT tolerated (0.38); PolyPhen possibly damaging (0.631); catalogued as rs750994811; called by muse, varscan2
- PPP1R3A | c.713C>G p.P238R | Missense Mutation (SNP) | VAF 35/83 reads (42%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.609); catalogued as COSV99492012; called by muse, mutect2, varscan2
- PRDM2 | c.197G>T p.R66I | Missense Mutation (SNP) | VAF 75/306 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99340446; called by muse, mutect2, varscan2
- PRDX1 | c.443C>T p.P148L | Missense Mutation (SNP) | VAF 119/680 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs1423630080; called by muse, mutect2, varscan2
- PROM1 | c.2533G>A p.G845S | Missense Mutation (SNP) | VAF 40/144 reads (28%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.634); catalogued as rs764991143; called by muse, mutect2
- PROS1 | c.850-1G>A p.X284_splice | Splice Site (SNP) | VAF 110/433 reads (25%) | catalogued as rs757532271, CS163629; called by muse, mutect2, varscan2
- PRR30 | c.119C>T p.P40L | Missense Mutation (SNP) | VAF 67/194 reads (35%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as rs767357441, COSV53207464; called by muse, mutect2, varscan2
- PRR9 | c.271G>T p.E91* | Nonsense Mutation (SNP) | VAF 1160/1456 reads (80%) | catalogued as rs1304994661; called by muse, varscan2
- PTPN13 | c.1555G>T p.D519Y | Missense Mutation (SNP) | VAF 117/598 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV57401411; called by muse, mutect2, varscan2
- PTPRD | c.5692C>T p.R1898C | Missense Mutation (SNP) | VAF 315/921 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as rs150063446, COSV61934701; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PTPRN | c.1913C>A p.T638K | Missense Mutation (SNP) | VAF 92/511 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.051); catalogued as rs765350345; called by muse, mutect2, varscan2
- PYGM | c.1525G>A p.G509R | Missense Mutation (SNP) | VAF 222/577 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs755309894; called by muse, mutect2, varscan2
- QSOX2 | c.988G>T p.G330W | Missense Mutation (SNP) | VAF 186/387 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV100699724; called by muse, mutect2, varscan2
- RAB3IL1 | c.514G>A p.E172K | Missense Mutation (SNP) | VAF 86/189 reads (46%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.483); catalogued as rs1303912170, COSV100076750; called by muse, mutect2, varscan2
- RAD51AP2 | c.3046G>T p.D1016Y | Missense Mutation (SNP) | VAF 37/117 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.891); catalogued as rs780875842, COSV67587435; called by muse, mutect2, varscan2
- RASGRP3 | c.831G>T p.L277F | Missense Mutation (SNP) | VAF 53/305 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs779293482; called by muse, mutect2, varscan2
- RD3 | c.437C>A p.P146H | Missense Mutation (SNP) | VAF 74/407 reads (18%) | SIFT tolerated (0.42); PolyPhen benign (0.023); catalogued as COSV65361967; called by muse, mutect2, varscan2
- REG1B | c.53C>G p.S18C | Missense Mutation (SNP) | VAF 35/295 reads (12%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.972); catalogued as rs753317922, COSV59307865; called by muse, mutect2, varscan2
- RELB | c.1259G>T p.G420V | Missense Mutation (SNP) | VAF 118/373 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.724); catalogued as COSV99672793; called by muse, mutect2, varscan2
- RPS6KA1 | c.158G>T p.G53V | Missense Mutation (SNP) | VAF 171/434 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1456649612; called by muse, mutect2, varscan2
- RSF1 | c.1973G>T p.G658V | Missense Mutation (SNP) | VAF 258/889 reads (29%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0); catalogued as rs1415865706; called by muse, mutect2, varscan2
- RXYLT1 | c.593T>C p.V198A | Missense Mutation (SNP) | VAF 53/401 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV99707132; called by muse, mutect2, varscan2
- RYR1 | c.496G>A p.D166N | Missense Mutation (SNP) | VAF 310/943 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs193922755, CM023443, COSV62105562; ClinVar: not provided; called by muse, mutect2, varscan2
- RYR1 | c.2108G>A p.G703D | Missense Mutation (SNP) | VAF 80/250 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1448234735; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SAMD7 | c.892C>A p.P298T | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT tolerated (0.08); PolyPhen benign (0.014); catalogued as COSV59419327, COSV59421518; called by muse, mutect2, varscan2
- SAMM50 | c.1247G>T p.R416L | Missense Mutation (SNP) | VAF 168/332 reads (51%) | SIFT tolerated (0.08); PolyPhen benign (0.022); catalogued as COSV63110058; called by muse, mutect2, varscan2
- SCN1B | c.179G>T p.R60L | Missense Mutation (SNP) | VAF 175/507 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.801); catalogued as COSV52893805, COSV99386426; called by muse, mutect2, varscan2
- SCN5A | c.2957G>T p.R986L | Missense Mutation (SNP) | VAF 85/160 reads (53%) | SIFT tolerated (0.63); PolyPhen benign (0); catalogued as rs41313667, CM157157, COSV61126581; called by muse, mutect2, varscan2
- SERPINB11 | c.1020C>G p.S340R | Missense Mutation (SNP) | VAF 107/402 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.065); catalogued as rs760266308, COSV66957141; called by muse, mutect2, varscan2
- SETBP1 | c.335G>T p.R112L | Missense Mutation (SNP) | VAF 213/1121 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56323096; called by muse, mutect2, varscan2
- SH3PXD2B | c.2386C>A p.R796S | Missense Mutation (SNP) | VAF 141/354 reads (40%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.168); catalogued as COSV61124500; called by muse, mutect2, varscan2
- SIGLEC1 | c.3221G>T p.G1074V | Missense Mutation (SNP) | VAF 32/136 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs776471499; called by muse, mutect2
- SIGLEC12 | c.1670C>T p.S557F (on ENST00000291707 / NM_053003.4; = p.S439F on NM_033329.2) | Missense Mutation (SNP) | VAF 53/185 reads (29%) | SIFT deleterious (0.03); PolyPhen benign (0.04); catalogued as rs1209817334, COSV52461558; called by muse, mutect2, varscan2
- SLC17A1 | c.1217G>T p.G406V | Missense Mutation (SNP) | VAF 39/343 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.733); catalogued as COSV55076961; called by muse, mutect2, varscan2
- SLIT2 | c.3343C>T p.P1115S | Missense Mutation (SNP) | VAF 62/344 reads (18%) | SIFT deleterious (0.04); PolyPhen benign (0.018); catalogued as rs748811402; called by muse, mutect2, varscan2
- SNAP91 | c.637G>A p.D213N | Missense Mutation (SNP) | VAF 23/111 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV52131573; called by muse, mutect2, varscan2
- SNX27 | c.788C>T p.S263L | Missense Mutation (SNP) | VAF 38/1218 reads (3%) | SIFT tolerated (0.08); PolyPhen benign (0.117); catalogued as COSV100918967; called by muse, mutect2
- SPOCK1 | c.800C>T p.S267L | Missense Mutation (SNP) | VAF 111/329 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.341); catalogued as rs371688944, COSV56450294; called by muse, mutect2, varscan2
- SPTAN1 | c.3988C>T p.Q1330* | Nonsense Mutation (SNP) | VAF 184/393 reads (47%) | catalogued as COSV100823585; called by muse, mutect2, varscan2
- SPTBN4 | c.315G>T p.E105D | Missense Mutation (SNP) | VAF 31/103 reads (30%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.597); catalogued as COSV100149776; called by muse, mutect2, varscan2
- SPTBN5 | c.1471G>A p.D491N | Missense Mutation (SNP) | VAF 95/239 reads (40%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.802); catalogued as rs775330843; called by muse, mutect2, varscan2
- SRD5A1 | c.566G>A p.G189D | Missense Mutation (SNP) | VAF 99/318 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs200931485; called by muse, mutect2, varscan2
- SSTR4 | c.586G>T p.V196L | Missense Mutation (SNP) | VAF 40/93 reads (43%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.627); catalogued as COSV54797974; called by muse, mutect2, varscan2
- STAG1 | c.1909A>T p.S637C | Missense Mutation (SNP) | VAF 170/500 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); catalogued as COSV52622558; called by muse, mutect2, varscan2
- STPG3 | c.889C>T p.P297S (on ENST00000388931 / NM_001256699.1; = p.I291= on NM_001004353.3) | Missense Mutation (SNP) | VAF 88/190 reads (46%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.094); catalogued as COSV100546857; called by muse, mutect2, varscan2
- SYCP2L | c.2213C>A p.P738Q | Missense Mutation (SNP) | VAF 66/412 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.155); catalogued as COSV51657992; called by muse, mutect2, varscan2
- SYT10 | c.1318C>A p.P440T | Missense Mutation (SNP) | VAF 254/529 reads (48%) | SIFT deleterious (0.03); PolyPhen benign (0.28); catalogued as COSV57339909; called by muse, mutect2, varscan2
- SYT10 | c.736G>C p.E246Q | Missense Mutation (SNP) | VAF 41/306 reads (13%) | SIFT tolerated (0.08); PolyPhen benign (0.259); catalogued as COSV57345274; called by muse, varscan2
- TACC1 | c.1615G>A p.V539I | Missense Mutation (SNP) | VAF 97/510 reads (19%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.832); catalogued as rs377134778; called by muse, mutect2, varscan2
- TACC2 | c.3848C>T p.S1283F | Missense Mutation (SNP) | VAF 57/250 reads (23%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as rs771446927, COSV57756038; called by muse, mutect2, varscan2
- TARS2 | c.512+1G>T p.X171_splice | Splice Site (SNP) | VAF 764/1073 reads (71%) | catalogued as rs769650841; called by muse, mutect2, varscan2
- TAS2R31 | c.130G>T p.A44S | Missense Mutation (SNP) | VAF 165/1304 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); catalogued as rs370880260; called by muse, varscan2
- TAS2R5 | c.833G>C p.R278T | Missense Mutation (SNP) | VAF 124/498 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.033); catalogued as rs1188968800; called by muse, mutect2, varscan2
- TAS2R5 | c.834G>T p.R278S | Missense Mutation (SNP) | VAF 112/473 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.124); catalogued as rs1235403343; called by muse, varscan2
- TATDN1 | c.5G>A p.S2N | Missense Mutation (SNP) | VAF 87/224 reads (39%) | SIFT deleterious (0.04); PolyPhen benign (0.03); catalogued as rs778035105; called by muse, mutect2, varscan2
- TAX1BP1 | c.1201G>T p.V401L | Missense Mutation (SNP) | VAF 308/1221 reads (25%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs768281146; called by muse, mutect2, varscan2
- TCEA1 | c.316G>T p.E106* | Nonsense Mutation (SNP) | VAF 54/416 reads (13%) | catalogued as COSV67171992; called by muse, mutect2, varscan2
- TCF12 | c.752G>T p.G251V | Missense Mutation (SNP) | VAF 257/578 reads (44%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.497); catalogued as COSV51012088; called by muse, mutect2, varscan2
- TENM2 | c.323C>A p.S108Y | Missense Mutation (SNP) | VAF 261/748 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.664); catalogued as COSV72854337; called by muse, mutect2, varscan2
- THSD7A | c.4649T>A p.L1550H | Missense Mutation (SNP) | VAF 281/955 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as COSV68472219; called by muse, mutect2, varscan2
- THSD7A | c.1001C>T p.T334M | Missense Mutation (SNP) | VAF 40/160 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.513); catalogued as rs372956657; called by muse, mutect2
- TMEM129 | c.200C>T p.P67L | Missense Mutation (SNP) | VAF 64/172 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.796); catalogued as COSV57558830; called by muse, mutect2, varscan2
- TMEM42 | c.7G>C p.E3Q | Missense Mutation (SNP) | VAF 37/100 reads (37%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.029); catalogued as rs1035700756; called by muse, mutect2, varscan2
- TNR | c.2825G>T p.S942I | Missense Mutation (SNP) | VAF 103/265 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54917358; called by muse, mutect2, varscan2
- TNR | c.220C>A p.P74T | Missense Mutation (SNP) | VAF 201/551 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99687041, COSV99688435; called by muse, mutect2, varscan2
- TRAK2 | c.870G>T p.Q290H | Missense Mutation (SNP) | VAF 29/92 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV60272024; called by muse, mutect2, varscan2
- TRDN | c.439A>G p.K147E | Missense Mutation (SNP) | VAF 25/80 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.637); catalogued as rs554795197; called by muse, mutect2, varscan2
- TRIM66 | c.2597G>T p.R866L | Missense Mutation (SNP) | VAF 112/343 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV55127340, COSV55127972; called by muse, mutect2, varscan2
- TRIM7 | c.728G>A p.R243Q | Missense Mutation (SNP) | VAF 168/935 reads (18%) | SIFT tolerated (0.17); PolyPhen benign (0.003); catalogued as rs569307799, COSV51240620; called by muse, mutect2, varscan2
- TRIP11 | c.3491G>A p.R1164H | Missense Mutation (SNP) | VAF 55/242 reads (23%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.678); catalogued as rs776668031; called by muse, mutect2, varscan2
- TRPA1 | c.100G>T p.E34* | Nonsense Mutation (SNP) | VAF 126/773 reads (16%) | catalogued as rs559544590; called by muse, mutect2, varscan2
- TSKS | c.1228G>T p.E410* | Nonsense Mutation (SNP) | VAF 79/269 reads (29%) | catalogued as COSV55873047; called by muse, mutect2, varscan2
- TTC34 | c.1792C>A p.P598T | Missense Mutation (SNP) | VAF 13/103 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); catalogued as COSV69002541; called by muse, mutect2
- TTLL6 | c.499G>T p.G167W | Missense Mutation (SNP) | VAF 108/273 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs189634235; called by muse, mutect2, varscan2
- TTN | c.64314G>C p.K21438N (on ENST00000591111; = p.K14014N on NM_003319.4) | Missense Mutation (SNP) | VAF 53/453 reads (12%) | PolyPhen probably damaging (0.997); catalogued as rs1234500748, COSV59976780; called by muse, mutect2, varscan2
- TTN | c.62309C>A p.T20770K (on ENST00000591111; = p.T13346K on NM_003319.4) | Missense Mutation (SNP) | VAF 145/982 reads (15%) | PolyPhen probably damaging (0.975); catalogued as COSV60444000; called by mutect2, varscan2
- TTN | c.1030C>A p.P344T | Missense Mutation (SNP) | VAF 59/474 reads (12%) | PolyPhen probably damaging (0.999); catalogued as COSV59967898; called by muse, mutect2, varscan2
- TUT4 | c.4004A>T p.D1335V | Missense Mutation (SNP) | VAF 96/753 reads (13%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.929); catalogued as rs1232711001; called by muse, mutect2, varscan2
- UMOD | c.1028C>T p.S343L | Missense Mutation (SNP) | VAF 167/938 reads (18%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.642); catalogued as rs387907550, COSV56775644; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- USH2A | c.9385G>A p.D3129N | Missense Mutation (SNP) | VAF 72/630 reads (11%) | SIFT tolerated (0.16); PolyPhen benign (0.007); catalogued as COSV56407602, COSV56451594; called by muse, varscan2
- USP29 | c.1802C>G p.A601G | Missense Mutation (SNP) | VAF 120/588 reads (20%) | SIFT tolerated (0.18); PolyPhen benign (0.197); catalogued as COSV54147820; called by muse, mutect2
- USP29 | c.1804G>C p.D602H | Missense Mutation (SNP) | VAF 124/596 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.942); catalogued as COSV54141233; called by muse, mutect2
- VCAN | c.4552G>T p.G1518W | Missense Mutation (SNP) | VAF 144/358 reads (40%) | SIFT tolerated (0.16); PolyPhen benign (0.034); catalogued as rs1401201077, COSV99425837; called by muse, mutect2, varscan2
- VN1R2 | c.391C>A p.L131M | Missense Mutation (SNP) | VAF 59/230 reads (26%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as COSV99052514; called by muse, mutect2, varscan2
- WDFY3 | c.6647A>G p.E2216G | Missense Mutation (SNP) | VAF 83/346 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs1465859215; called by muse, mutect2, varscan2
- WDR73 | c.64G>T p.D22Y | Missense Mutation (SNP) | VAF 78/240 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); catalogued as rs1193605465; called by muse, mutect2, varscan2
- WNK1 | c.3790C>T p.P1264S (on ENST00000315939 / NM_018979.4; = p.P1017S on NM_014823.3) | Missense Mutation (SNP) | VAF 149/1132 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100266322; called by muse, mutect2, varscan2
- WNT7A | c.613G>T p.V205L | Missense Mutation (SNP) | VAF 54/93 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as rs1338142209, COSV53199258; called by muse, mutect2, varscan2
- YOD1 | c.257G>T p.G86V | Missense Mutation (SNP) | VAF 233/576 reads (40%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as rs770934117; called by muse, mutect2, varscan2
- ZACN | c.546G>A p.A182= | Splice Region (SNP) | VAF 105/305 reads (34%) | catalogued as rs755903885; called by muse, mutect2, varscan2
- ZFP91 | c.1330A>T p.S444C | Missense Mutation (SNP) | VAF 44/333 reads (13%) | SIFT tolerated (0.08); PolyPhen benign (0.02); catalogued as rs1388546356; called by muse, mutect2, varscan2
- ZFPM1 | c.2360C>T p.P787L | Missense Mutation (SNP) | VAF 31/94 reads (33%) | SIFT tolerated (0.17); PolyPhen benign (0.122); catalogued as rs754395840; called by muse, mutect2, varscan2
- ZKSCAN2 | c.46G>C p.E16Q | Missense Mutation (SNP) | VAF 24/128 reads (19%) | SIFT deleterious (0.04); PolyPhen benign (0.149); catalogued as COSV60156149; called by muse, mutect2
- ZMIZ2 | c.1517C>T p.S506L | Missense Mutation (SNP) | VAF 208/661 reads (31%) | SIFT deleterious (0.02); PolyPhen benign (0.291); catalogued as rs758496637; called by muse, mutect2, varscan2
- ZNF142 | c.48G>T p.E16D | Missense Mutation (SNP) | VAF 16/29 reads (55%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); catalogued as COSV63719709; called by muse, mutect2, varscan2
- ZNF254 | c.851A>G p.H284R | Missense Mutation (SNP) | VAF 64/176 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.265); catalogued as rs774137972; called by muse, mutect2, varscan2
- ZNF345 | c.413G>C p.R138T | Missense Mutation (SNP) | VAF 56/387 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.144); catalogued as rs375817401, COSV59325717; called by muse, mutect2, varscan2
- ZNF366 | c.1916G>T p.S639I | Missense Mutation (SNP) | VAF 46/244 reads (19%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.1); catalogued as rs1288291607, COSV59214605; called by muse, varscan2
- ZNF366 | c.400G>T p.V134L | Missense Mutation (SNP) | VAF 96/713 reads (13%) | SIFT tolerated, low confidence (0.34); PolyPhen benign (0.003); catalogued as rs778281671, COSV59216893; called by muse, mutect2, varscan2
- ZNF543 | c.1487G>C p.R496T | Missense Mutation (SNP) | VAF 170/626 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58627953; called by muse, mutect2, varscan2
- ZNF543 | c.1488G>T p.R496S | Missense Mutation (SNP) | VAF 166/623 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1440120917; called by muse, mutect2, varscan2
- ZNF598 | c.554G>T p.G185V | Missense Mutation (SNP) | VAF 226/583 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV70910835; called by muse, mutect2, varscan2
- ZNF652 | c.1633C>T p.H545Y | Missense Mutation (SNP) | VAF 33/167 reads (20%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0); catalogued as COSV62948352; called by muse, mutect2, varscan2
- ZNF80 | c.218G>T p.G73V | Missense Mutation (SNP) | VAF 72/208 reads (35%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as COSV100352098; called by muse, mutect2, varscan2
- ZNF831 | c.1331C>A p.T444K | Missense Mutation (SNP) | VAF 32/150 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.011); catalogued as COSV64038766; called by muse, varscan2
- ZYG11A | c.1460C>T p.A487V | Missense Mutation (SNP) | VAF 127/465 reads (27%) | SIFT tolerated (0.09); PolyPhen benign (0.105); catalogued as COSV65294370; called by muse, mutect2, varscan2
- AADACL3 | c.626G>T p.R209M | Missense Mutation (SNP) | VAF 52/246 reads (21%) | SIFT deleterious (0.04); PolyPhen benign (0.059); called by muse, mutect2, varscan2
- ABCA10 | c.3940G>C p.E1314Q | Missense Mutation (SNP) | VAF 44/360 reads (12%) | SIFT tolerated (0.32); PolyPhen possibly damaging (0.855); called by muse, mutect2, varscan2
- ABCA2 | c.1585G>A p.E529K (on ENST00000614293; = p.E499K on NM_001606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 154/309 reads (50%) | SIFT tolerated (0.29); PolyPhen benign (0.335); called by muse, mutect2, varscan2
- ABCA4 | c.6304G>C p.D2102H | Missense Mutation (SNP) | VAF 75/456 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ABCA8 | c.3377C>A p.T1126N | Missense Mutation (SNP) | VAF 162/322 reads (50%) | SIFT tolerated (0.07); PolyPhen benign (0.033); called by muse, varscan2
- ABCA9 | c.4675G>T p.E1559* | Nonsense Mutation (SNP) | VAF 103/558 reads (18%) | called by muse, mutect2, varscan2
- ABCG8 | c.364G>A p.G122S | Missense Mutation (SNP) | VAF 197/968 reads (20%) | SIFT tolerated (0.29); PolyPhen benign (0.078); called by muse, mutect2, varscan2
- ABHD1 | c.1005T>C p.C335= | Splice Region (SNP) | VAF 45/125 reads (36%) | called by muse, mutect2, varscan2
- AC048338.2 | c.56_65del p.F19Sfs*22 | Frame Shift Del (DEL) | VAF 65/425 reads (15%) | called by mutect2, pindel, varscan2
- ACACA | c.1691A>C p.Q564P | Missense Mutation (SNP) | VAF 136/830 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.92); called by muse, mutect2, varscan2
- ACADS | c.694G>A p.G232S | Missense Mutation (SNP) | VAF 110/359 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ACCSL | c.763G>T p.D255Y | Missense Mutation (SNP) | VAF 121/689 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- ACOD1 | c.563T>A p.L188Q | Missense Mutation (SNP) | VAF 446/740 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- ACOX1 | c.1548G>A p.W516* | Nonsense Mutation (SNP) | VAF 168/901 reads (19%) | called by muse, mutect2, varscan2
- ACSM2A | c.1498G>T p.V500F (on ENST00000219054; = p.V421F on NM_001308169.2) | Missense Mutation (SNP) | VAF 180/588 reads (31%) | SIFT tolerated (0.07); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- ADAMTS14 | c.32T>A p.L11Q | Missense Mutation (SNP) | VAF 193/365 reads (53%) | SIFT deleterious (0); PolyPhen possibly damaging (0.585); called by muse, mutect2, varscan2
- ADAMTS16 | c.3348G>T p.R1116S | Missense Mutation (SNP) | VAF 112/385 reads (29%) | SIFT tolerated (0.68); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- ADAMTS17 | c.1618G>A p.E540K | Missense Mutation (SNP) | VAF 82/288 reads (28%) | SIFT deleterious (0.05); PolyPhen benign (0.034); called by muse, mutect2, varscan2
- ADAMTS19 | c.154G>A p.E52K | Missense Mutation (SNP) | VAF 37/176 reads (21%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.083); called by muse, mutect2, varscan2
- ADAMTS9 | c.1871G>T p.G624V | Missense Mutation (SNP) | VAF 35/186 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- ADCY10 | c.3481C>T p.L1161F | Missense Mutation (SNP) | VAF 110/641 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ADGRB1 | c.3846C>A p.N1282K | Missense Mutation (SNP) | VAF 69/392 reads (18%) | SIFT tolerated (0.05); PolyPhen benign (0.091); called by muse, mutect2, varscan2
- ADGRD2 | c.1618G>T p.E540* | Nonsense Mutation (SNP) | VAF 17/45 reads (38%) | called by muse, mutect2, varscan2
- ADGRL3 | c.327del p.I109Mfs*12 (on ENST00000506720 / NM_001322402.2; = p.I41Mfs*12 on NM_015236.6) | Frame Shift Del (DEL) | VAF 66/525 reads (13%) | called by mutect2, pindel, varscan2
- ADGRL3 | c.4069C>A p.R1357S (on ENST00000506720 / NM_001322402.2; = p.R1246S on NM_015236.6) | Missense Mutation (SNP) | VAF 138/861 reads (16%) | SIFT tolerated (0.81); PolyPhen possibly damaging (0.866); called by muse, mutect2, varscan2
- ADGRV1 | c.5441G>T p.G1814V | Missense Mutation (SNP) | VAF 25/311 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.993); called by muse, mutect2
- ADGRV1 | c.5442A>T p.G1814= | Splice Region (SNP) | VAF 25/310 reads (8%) | called by muse, mutect2
- ADORA1 | c.871C>G p.R291G | Missense Mutation (SNP) | VAF 17/102 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- ADORA2A | c.133G>T p.V45L | Missense Mutation (SNP) | VAF 140/302 reads (46%) | SIFT tolerated (0.54); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- AEBP1 | c.1097-2A>G p.X366_splice | Splice Site (SNP) | VAF 16/62 reads (26%) | called by muse, mutect2, varscan2
- AGAP2 | c.2255G>T p.S752I (on ENST00000547588 / NM_001122772.2; = p.S416I on NM_014770.4) | Missense Mutation (SNP) | VAF 87/261 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.563); called by muse, mutect2, varscan2
- AGFG1 | c.472A>T p.K158* | Nonsense Mutation (SNP) | VAF 143/599 reads (24%) | called by muse, mutect2, varscan2
- AGR2 | c.410_413del p.V137Efs*27 | Frame Shift Del (DEL) | VAF 126/675 reads (19%) | called by mutect2, pindel, varscan2
- AHDC1 | c.439T>A p.C147S | Missense Mutation (SNP) | VAF 89/211 reads (42%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.765); called by muse, mutect2, varscan2
- ALOX5 | c.1818G>T p.W606C | Missense Mutation (SNP) | VAF 91/171 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- ALOX5AP | c.259G>A p.G87R | Missense Mutation (SNP) | VAF 108/284 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ALPK2 | c.5620A>C p.T1874P | Missense Mutation (SNP) | VAF 52/210 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); called by muse, mutect2, varscan2
- AMMECR1 | c.188G>T p.G63V | Missense Mutation (SNP) | VAF 49/108 reads (45%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0); called by muse, mutect2, varscan2
- AMPD3 | c.30C>G p.I10M (on ENST00000396553 / NM_001025389.2; = p.I19M on NM_000480.3) | Missense Mutation (SNP) | VAF 202/1230 reads (16%) | SIFT tolerated (0.22); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ANGPT1 | c.453+1G>T p.X151_splice | Splice Site (SNP) | VAF 12/177 reads (7%) | called by muse, mutect2
- ANK3 | c.1293G>A p.E431= | Splice Region (SNP) | VAF 116/257 reads (45%) | called by muse, mutect2, varscan2
- ANKIB1 | c.2996C>T p.S999F | Missense Mutation (SNP) | VAF 174/449 reads (39%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- ANKRD20A2P | c.2380G>C p.E794Q | Missense Mutation (SNP) | VAF 13/94 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.931); called by mutect2, varscan2
- ANKRD30A | c.1708-1G>T p.X570_splice (on ENST00000611781; = p.X514_splice on NM_052997.2) | Splice Site (SNP) | VAF 96/831 reads (12%) | called by muse, varscan2
- ANKRD30A | c.2065-1G>T p.X689_splice (on ENST00000611781; = p.X633_splice on NM_052997.2) | Splice Site (SNP) | VAF 18/162 reads (11%) | called by mutect2, varscan2
- ANKRD30A | c.2422-1G>T p.X808_splice (on ENST00000611781; = p.X752_splice on NM_052997.2) | Splice Site (SNP) | VAF 16/54 reads (30%) | called by mutect2, varscan2
- APOB | c.12142T>C p.S4048P | Missense Mutation (SNP) | VAF 187/478 reads (39%) | SIFT tolerated (0.37); PolyPhen benign (0.045); called by muse, mutect2, varscan2
- APOB | c.7790T>A p.M2597K | Missense Mutation (SNP) | VAF 234/630 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.188); called by muse, mutect2, varscan2
- APOB | c.3420C>A p.H1140Q | Missense Mutation (SNP) | VAF 106/636 reads (17%) | SIFT tolerated (0.77); PolyPhen possibly damaging (0.494); called by muse, mutect2, varscan2
- ARFGEF3 | c.2484T>G p.S828R | Missense Mutation (SNP) | VAF 270/560 reads (48%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.518); called by muse, mutect2, varscan2
- ARL5A | c.255+1G>A p.X85_splice | Splice Site (SNP) | VAF 24/49 reads (49%) | called by muse, varscan2
- ARMCX2 | c.1202C>G p.P401R | Missense Mutation (SNP) | VAF 68/253 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ARMCX5 | c.1112G>A p.G371E | Missense Mutation (SNP) | VAF 73/163 reads (45%) | SIFT deleterious (0.01); PolyPhen benign (0.028); called by muse, mutect2, varscan2
- ARMH4 | c.106G>T p.E36* | Nonsense Mutation (SNP) | VAF 92/365 reads (25%) | called by muse, mutect2, varscan2
- ARPC3 | c.437A>C p.E146A | Missense Mutation (SNP) | VAF 69/603 reads (11%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.77); called by muse, mutect2, varscan2
- ASIC3 | c.401C>A p.A134E | Missense Mutation (SNP) | VAF 95/420 reads (23%) | SIFT tolerated (1); PolyPhen benign (0.078); called by muse, mutect2, varscan2
- ASTE1 | c.1491G>C p.L497F | Missense Mutation (SNP) | VAF 93/574 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- ASTN2 | c.230G>C p.R77P | Missense Mutation (SNP) | VAF 89/157 reads (57%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.599); called by muse, mutect2, varscan2
- ASXL3 | c.1259C>A p.A420D | Missense Mutation (SNP) | VAF 123/503 reads (24%) | SIFT tolerated, low confidence (0.36); PolyPhen benign (0); called by muse, mutect2, varscan2
- ATF7IP | c.2298G>T p.Q766H | Missense Mutation (SNP) | VAF 475/944 reads (50%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ATP13A5 | c.2679A>T p.R893S | Missense Mutation (SNP) | VAF 35/241 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.211); called by muse, mutect2, varscan2
- ATP7A | c.1336+1G>T p.X446_splice | Splice Site (SNP) | VAF 46/153 reads (30%) | called by muse, mutect2, varscan2
- AWAT2 | c.523G>T p.G175C | Missense Mutation (SNP) | VAF 174/412 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- B2M | c.43_44del p.L15Ffs*41 | Frame Shift Del (DEL) | VAF 193/1052 reads (18%) | called by pindel, varscan2
- B3GALT1 | c.349C>A p.L117I | Missense Mutation (SNP) | VAF 32/192 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.957); called by muse, mutect2, varscan2
- B4GALNT2 | c.860-1G>T p.X287_splice | Splice Site (SNP) | VAF 171/410 reads (42%) | called by muse, mutect2, varscan2
- BABAM2 | c.148G>T p.G50W | Missense Mutation (SNP) | VAF 172/737 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.956); called by muse, mutect2, varscan2
- BABAM2 | c.149G>T p.G50V | Missense Mutation (SNP) | VAF 175/741 reads (24%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.589); called by muse, mutect2, varscan2
- BAZ1A | c.4160A>T p.Q1387L | Missense Mutation (SNP) | VAF 50/351 reads (14%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- BCL6 | c.2035C>T p.Q679* | Nonsense Mutation (SNP) | VAF 79/466 reads (17%) | called by muse, mutect2, varscan2
- BICDL1 | c.1178C>T p.S393F | Missense Mutation (SNP) | VAF 115/610 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- BLK | c.275G>T p.G92V | Missense Mutation (SNP) | VAF 162/671 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by mutect2, varscan2
- BLOC1S3 | c.572G>T p.G191V | Missense Mutation (SNP) | VAF 163/478 reads (34%) | SIFT tolerated (0.15); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- BOC | c.775C>A p.P259T | Missense Mutation (SNP) | VAF 142/916 reads (16%) | SIFT tolerated (0.41); PolyPhen benign (0.173); called by muse, mutect2, varscan2
- BPI | c.203A>C p.Y68S (on ENST00000262865; = p.Y64S on NM_001725.3) | Missense Mutation (SNP) | VAF 65/328 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.162); called by muse, mutect2, varscan2
- BRIP1 | c.1970G>T p.G657V | Missense Mutation (SNP) | VAF 125/1174 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- BTN3A3 | c.192G>T p.E64D | Missense Mutation (SNP) | VAF 165/1365 reads (12%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- C12orf42 | c.961C>A p.H321N | Missense Mutation (SNP) | VAF 34/153 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- C12orf56 | c.1606G>A p.V536M (on ENST00000543942 / NM_001170633.2; = p.V376M on NM_001099676.3) | Missense Mutation (SNP) | VAF 78/173 reads (45%) | SIFT tolerated (0.06); PolyPhen benign (0.178); called by muse, mutect2, varscan2
- C1orf198 | c.553G>T p.E185* | Nonsense Mutation (SNP) | VAF 62/212 reads (29%) | called by muse, mutect2, varscan2
- C2CD4D | c.923A>C p.K308T | Missense Mutation (SNP) | VAF 90/1418 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- C2orf80 | c.83A>T p.D28V | Missense Mutation (SNP) | VAF 46/668 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- C7 | c.2020G>T p.G674C | Missense Mutation (SNP) | VAF 55/152 reads (36%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.967); called by muse, mutect2, varscan2
- CACNA1S | c.1233C>G p.I411M | Missense Mutation (SNP) | VAF 242/623 reads (39%) | SIFT tolerated (0.22); PolyPhen benign (0.044); called by muse, mutect2, varscan2
- CACNA2D1 | c.3036C>A p.N1012K (on ENST00000356253 / NM_001366867.1; = p.N1000K on NM_000722.4) | Missense Mutation (SNP) | VAF 209/775 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- CALB2 | c.459G>T p.Q153H | Missense Mutation (SNP) | VAF 54/246 reads (22%) | SIFT tolerated (0.12); PolyPhen benign (0.007); called by muse, varscan2
- CBR4 | c.250G>T p.A84S | Missense Mutation (SNP) | VAF 20/117 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CBWD5 | c.1093G>T p.D365Y (on ENST00000382405 / NM_001330668.1; = p.D317Y on NM_001024916.3) | Missense Mutation (SNP) | VAF 12/74 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.457); called by mutect2, varscan2
- CCDC136 | c.108A>T p.K36N | Missense Mutation (SNP) | VAF 112/408 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- CCDC166 | c.710G>C p.R237P | Missense Mutation (SNP) | VAF 26/104 reads (25%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.905); called by muse, mutect2, varscan2
- CCDC47 | c.622T>A p.W208R | Missense Mutation (SNP) | VAF 78/899 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- CCDC81 | c.141G>T p.K47N | Missense Mutation (SNP) | VAF 38/289 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CCT6B | c.638A>T p.D213V | Missense Mutation (SNP) | VAF 53/259 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- CD177 | c.1021del p.R341Efs*2 | Frame Shift Del (DEL) | VAF 48/112 reads (43%) | called by mutect2, varscan2
- CD36 | c.717G>T p.W239C | Missense Mutation (SNP) | VAF 188/665 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- CD79B | c.179C>A p.T60K | Missense Mutation (SNP) | VAF 69/500 reads (14%) | SIFT tolerated (0.94); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- CDH17 | c.1509C>A p.D503E | Missense Mutation (SNP) | VAF 90/226 reads (40%) | SIFT tolerated (1); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- CDH20 | c.1587del p.Y530Tfs*16 | Frame Shift Del (DEL) | VAF 88/550 reads (16%) | called by mutect2, pindel, varscan2
- CDH22 | c.299C>A p.T100N | Missense Mutation (SNP) | VAF 48/222 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.891); called by muse, mutect2, varscan2
- CDH6 | c.1054C>A p.P352T | Missense Mutation (SNP) | VAF 141/485 reads (29%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- CDO1 | c.442A>G p.T148A | Missense Mutation (SNP) | VAF 124/862 reads (14%) | SIFT tolerated (0.19); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- CEACAM18 | c.596A>T p.D199V | Missense Mutation (SNP) | VAF 152/476 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- CELA3B | c.726T>A p.F242L | Missense Mutation (SNP) | VAF 94/426 reads (22%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- CENPJ | c.749G>A p.G250E | Missense Mutation (SNP) | VAF 261/651 reads (40%) | SIFT tolerated (0.99); PolyPhen benign (0); called by muse, mutect2, varscan2
- CEP120 | c.2050G>T p.A684S | Missense Mutation (SNP) | VAF 112/471 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CEP135 | c.1107G>T p.Q369H | Missense Mutation (SNP) | VAF 22/165 reads (13%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.743); called by muse, mutect2, varscan2
- CEP89 | c.887-2A>T p.X296_splice | Splice Site (SNP) | VAF 112/347 reads (32%) | called by muse, mutect2, varscan2
- CEP97 | c.508A>G p.R170G | Missense Mutation (SNP) | VAF 86/347 reads (25%) | SIFT tolerated (0.16); PolyPhen benign (0.191); called by muse, mutect2, varscan2
- CERKL | c.482-2A>T p.X161_splice | Splice Site (SNP) | VAF 44/275 reads (16%) | called by muse, mutect2, varscan2
- CFAP44 | c.3553C>T p.P1185S | Missense Mutation (SNP) | VAF 66/629 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.852); called by muse, mutect2, varscan2
- CFAP47 | c.9221G>T p.G3074V | Missense Mutation (SNP) | VAF 197/492 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.872); called by muse, mutect2, varscan2
- CFAP65 | c.2492C>T p.P831L | Missense Mutation (SNP) | VAF 354/700 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, varscan2
- CFAP92 | c.1918G>C p.V640L | Missense Mutation (SNP) | VAF 101/283 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); called by muse, mutect2, varscan2
- CHD8 | c.5062G>A p.D1688N (on ENST00000646647 / NM_001170629.2; = p.D1409N on NM_020920.4) | Missense Mutation (SNP) | VAF 31/271 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- CHD8 | c.1678G>C p.A560P (on ENST00000646647 / NM_001170629.2; = p.A281P on NM_020920.4) | Missense Mutation (SNP) | VAF 40/486 reads (8%) | SIFT tolerated (0.77); PolyPhen benign (0.001); called by muse, mutect2
- CHP2 | c.503G>T p.G168V | Missense Mutation (SNP) | VAF 38/164 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.825); called by muse, mutect2, varscan2
- CHRM1 | c.747G>C p.E249D | Missense Mutation (SNP) | VAF 38/164 reads (23%) | SIFT tolerated (0.55); PolyPhen benign (0); called by muse, mutect2, varscan2
- CHRM2 | c.1082T>C p.V361A | Missense Mutation (SNP) | VAF 339/922 reads (37%) | SIFT tolerated (0.67); PolyPhen benign (0.145); called by muse, mutect2, varscan2
- CLCN3 | c.2017G>C p.D673H | Missense Mutation (SNP) | VAF 41/251 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.841); called by muse, mutect2, varscan2
- CLEC19A | c.341A>T p.H114L | Missense Mutation (SNP) | VAF 107/707 reads (15%) | SIFT tolerated (0.26); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CLEC4A | c.451G>A p.D151N | Missense Mutation (SNP) | VAF 237/401 reads (59%) | SIFT deleterious (0.03); PolyPhen benign (0.17); called by muse, mutect2, varscan2
- CLRN2 | c.189C>G p.Y63* | Nonsense Mutation (SNP) | VAF 141/435 reads (32%) | called by muse, mutect2, varscan2
- CLUH | c.1690C>T p.L564F (on ENST00000435359; = p.L602F on NM_015229.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 137/261 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CMA1 | c.245C>G p.T82R | Missense Mutation (SNP) | VAF 68/219 reads (31%) | SIFT tolerated (0.22); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- CNTN5 | c.679A>G p.I227V | Missense Mutation (SNP) | VAF 48/424 reads (11%) | SIFT tolerated (0.6); PolyPhen benign (0.442); called by muse, mutect2, varscan2
- CNTNAP3 | c.1581C>G p.I527M | Missense Mutation (SNP) | VAF 55/572 reads (10%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.632); called by muse, mutect2, varscan2
- COG6 | c.622G>T p.G208C | Missense Mutation (SNP) | VAF 304/881 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.492); called by muse, mutect2, varscan2
- COL11A1 | c.1736G>T p.R579M | Missense Mutation (SNP) | VAF 152/954 reads (16%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.993); called by mutect2, varscan2
- COL1A1 | c.1346G>A p.G449E | Missense Mutation (SNP) | VAF 77/628 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- COL21A1 | c.583del p.E195Kfs*9 | Frame Shift Del (DEL) | VAF 41/178 reads (23%) | called by mutect2, pindel, varscan2
- COL2A1 | c.661C>A p.Q221K | Missense Mutation (SNP) | VAF 235/1101 reads (21%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.973); called by muse, mutect2, varscan2
- COL4A4 | c.622G>T p.G208C | Missense Mutation (SNP) | VAF 207/1339 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- COL6A6 | c.883C>A p.H295N | Missense Mutation (SNP) | VAF 94/661 reads (14%) | SIFT tolerated (0.19); PolyPhen benign (0); called by muse, mutect2, varscan2
- COL8A2 | c.1121C>A p.P374H | Missense Mutation (SNP) | VAF 74/192 reads (39%) | SIFT tolerated (0.54); PolyPhen benign (0.044); called by muse, mutect2, varscan2
- COMMD3-BMI1 | c.391G>T p.A131S | Missense Mutation (SNP) | VAF 32/106 reads (30%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.308); called by muse, mutect2, varscan2
- COPB1 | c.1453G>C p.E485Q | Missense Mutation (SNP) | VAF 75/541 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.875); called by muse, mutect2, varscan2
- COX7A1 | c.4C>A p.Q2K | Missense Mutation (SNP) | VAF 31/77 reads (40%) | SIFT tolerated (0.14); PolyPhen benign (0); called by muse, mutect2, varscan2
- CRY2 | c.1292G>T p.C431F | Missense Mutation (SNP) | VAF 84/246 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.898); called by muse, mutect2, varscan2
- CRYBG3 | c.7865A>T p.K2622M | Missense Mutation (SNP) | VAF 51/189 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- CSNK2A2 | c.430G>T p.A144S | Missense Mutation (SNP) | VAF 34/212 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.908); called by muse, mutect2, varscan2
- CSNK2A2 | c.430-1G>A p.X144_splice | Splice Site (SNP) | VAF 30/206 reads (15%) | called by muse, mutect2, varscan2
- CST7 | c.65C>A p.S22Y | Missense Mutation (SNP) | VAF 93/254 reads (37%) | SIFT tolerated (0.49); PolyPhen benign (0.055); called by muse, mutect2, varscan2
- CTNNA2 | c.1717G>C p.A573P | Missense Mutation (SNP) | VAF 6/90 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.906); called by muse, mutect2
- CYP26B1 | c.749C>A p.A250D | Missense Mutation (SNP) | VAF 161/894 reads (18%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.463); called by muse, mutect2, varscan2
- DBF4 | c.400-2A>T p.X134_splice | Splice Site (SNP) | VAF 100/429 reads (23%) | called by muse, mutect2, varscan2
- DCC | c.2148dup p.E717Rfs*3 | Frame Shift Ins (INS) | VAF 67/534 reads (13%) | called by mutect2, pindel, varscan2
- DCHS2 | n.693+1G>T | Splice Site (SNP) | VAF 38/190 reads (20%) | called by muse, mutect2, varscan2
- DCLK3 | c.376G>T p.G126W | Missense Mutation (SNP) | VAF 15/25 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- DCST2 | c.1630T>A p.Y544N | Missense Mutation (SNP) | VAF 31/669 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.967); called by muse, mutect2
- DCT | c.263G>T p.R88I | Missense Mutation (SNP) | VAF 167/229 reads (73%) | SIFT tolerated (0.22); PolyPhen benign (0.122); called by muse, mutect2, varscan2
- DCUN1D4 | c.149C>T p.S50F | Missense Mutation (SNP) | VAF 83/222 reads (37%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.092); called by muse, mutect2, varscan2
- DEDD2 | c.532G>T p.A178S | Missense Mutation (SNP) | VAF 58/205 reads (28%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- DENND2C | c.1949G>C p.G650A (on ENST00000393274 / NM_001256404.2; = p.G593A on NM_198459.4) | Missense Mutation (SNP) | VAF 45/238 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- DHX38 | c.2131G>A p.V711I | Missense Mutation (SNP) | VAF 45/240 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- DHX57 | c.1474G>C p.E492Q | Missense Mutation (SNP) | VAF 93/594 reads (16%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.811); called by muse, mutect2, varscan2
- DHX8 | c.41C>G p.S14W | Missense Mutation (SNP) | VAF 81/473 reads (17%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.124); called by muse, mutect2, varscan2
- DLG5 | c.2770G>T p.G924C | Missense Mutation (SNP) | VAF 112/221 reads (51%) | SIFT deleterious (0.05); PolyPhen benign (0.401); called by muse, mutect2, varscan2
- DNAH11 | c.1918C>G p.Q640E | Missense Mutation (SNP) | VAF 139/670 reads (21%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- DNAH11 | c.11783C>A p.P3928H | Missense Mutation (SNP) | VAF 83/259 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DNAH14 | c.1855C>T p.Q619* (on ENST00000445597; = p.Q648* on NM_001367479.1) | Nonsense Mutation (SNP) | VAF 45/147 reads (31%) | called by muse, mutect2, varscan2
- DNAH6 | c.103A>T p.R35* | Nonsense Mutation (SNP) | VAF 83/312 reads (27%) | called by muse, mutect2, varscan2
- DNAH6 | c.12139dup p.M4047Nfs*9 | Frame Shift Ins (INS) | VAF 44/302 reads (15%) | called by pindel, varscan2
- DNAH9 | c.3611dup p.A1205Gfs*15 | Frame Shift Ins (INS) | VAF 122/356 reads (34%) | called by mutect2, pindel, varscan2
- DNAH9 | c.13273C>A p.P4425T | Missense Mutation (SNP) | VAF 164/359 reads (46%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- DNHD1 | c.13225C>A p.Q4409K | Missense Mutation (SNP) | VAF 123/668 reads (18%) | SIFT tolerated (0.13); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- DNMT3B | c.714G>T p.W238C | Missense Mutation (SNP) | VAF 304/798 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DPEP1 | c.1126T>C p.S376P | Missense Mutation (SNP) | VAF 48/240 reads (20%) | SIFT tolerated (0.22); PolyPhen benign (0.001); called by muse, varscan2
- DPP6 | c.701C>A p.P234Q (on ENST00000377770 / NM_001364500.2; = p.P172Q on NM_001936.5) | Missense Mutation (SNP) | VAF 254/731 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- DRP2 | c.781G>T p.G261W | Missense Mutation (SNP) | VAF 131/262 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DSC1 | c.631T>C p.Y211H | Missense Mutation (SNP) | VAF 8/61 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); called by muse, varscan2
- DSCAM | c.3088G>T p.G1030W | Missense Mutation (SNP) | VAF 183/839 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.881); called by muse, mutect2, varscan2
- DST | c.13483G>T p.E4495* (on ENST00000361203 / NM_001374722.1; = p.E2083* on NM_015548.5) | Nonsense Mutation (SNP) | VAF 42/168 reads (25%) | called by muse, mutect2, varscan2
- DUS3L | c.1670G>T p.G557V | Missense Mutation (SNP) | VAF 94/236 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- DYSF | c.3231del p.W1077* | Frame Shift Del (DEL) | VAF 50/354 reads (14%) | called by mutect2, pindel, varscan2
- E2F8 | c.119G>T p.G40V | Missense Mutation (SNP) | VAF 264/885 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.794); called by muse, mutect2, varscan2
- EBF1 | c.947C>A p.P316H | Missense Mutation (SNP) | VAF 56/218 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ECM1 | c.109C>T p.H37Y | Missense Mutation (SNP) | VAF 324/2631 reads (12%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- EEA1 | c.3355C>G p.L1119V | Missense Mutation (SNP) | VAF 22/163 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- EFCAB6 | c.3229G>A p.A1077T | Missense Mutation (SNP) | VAF 11/23 reads (48%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.599); called by muse, mutect2, varscan2
- EMILIN2 | c.2103G>A p.M701I | Missense Mutation (SNP) | VAF 19/113 reads (17%) | SIFT tolerated (0.23); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- EML6 | c.1797C>A p.S599R | Missense Mutation (SNP) | VAF 93/284 reads (33%) | SIFT tolerated (0.52); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- EPHA6 | c.1536G>C p.M512I | Missense Mutation (SNP) | VAF 54/430 reads (13%) | SIFT tolerated (0.06); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- ERVV-1 | c.812C>A p.P271H | Missense Mutation (SNP) | VAF 250/1030 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); called by muse, varscan2
- ERVW-1 | c.843T>A p.N281K | Missense Mutation (SNP) | VAF 90/252 reads (36%) | SIFT tolerated (0.09); PolyPhen benign (0.116); called by muse, mutect2, varscan2
- EXOC8 | c.1712C>G p.S571C | Missense Mutation (SNP) | VAF 138/678 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- EXT1 | c.2195A>T p.Q732L | Missense Mutation (SNP) | VAF 126/858 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.299); called by muse, mutect2, varscan2
- FABP12 | c.246+6G>A | Splice Region (SNP) | VAF 283/812 reads (35%) | called by muse, mutect2, varscan2
- FAM133B | c.590A>C p.E197A | Missense Mutation (SNP) | VAF 48/167 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.391); called by muse, varscan2
- FAM184B | c.2096C>A p.T699K | Missense Mutation (SNP) | VAF 172/489 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- FAM186B | c.837C>A p.F279L | Missense Mutation (SNP) | VAF 36/90 reads (40%) | SIFT tolerated (0.1); PolyPhen benign (0.435); called by muse, mutect2, varscan2
- FAM47C | c.2196G>T p.E732D | Missense Mutation (SNP) | VAF 355/770 reads (46%) | SIFT tolerated (0.15); PolyPhen benign (0.413); called by muse, mutect2, varscan2
- FAM71B | c.1347del p.G450Vfs*39 | Frame Shift Del (DEL) | VAF 124/348 reads (36%) | called by mutect2, pindel*, varscan2
- FAM83C | c.2201A>T p.N734I | Missense Mutation (SNP) | VAF 42/224 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.909); called by muse, mutect2
- FAT3 | c.11422A>T p.M3808L | Missense Mutation (SNP) | VAF 265/759 reads (35%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.938); called by muse, mutect2, varscan2
- FBH1 | c.85G>T p.G29C (on ENST00000362091 / NM_178150.3; = p.G80C on NM_032807.4) | Missense Mutation (SNP) | VAF 67/397 reads (17%) | SIFT deleterious (0.05); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- FBRSL1 | c.2509G>C p.A837P | Missense Mutation (SNP) | VAF 12/121 reads (10%) | SIFT tolerated (0.06); PolyPhen benign (0.036); called by muse, mutect2
- FBXO27 | c.124C>A p.P42T | Missense Mutation (SNP) | VAF 75/237 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.894); called by muse, mutect2, varscan2
- FBXO38 | c.679A>T p.K227* | Nonsense Mutation (SNP) | VAF 45/321 reads (14%) | called by muse, mutect2, varscan2
- FBXO38 | c.2474C>T p.S825F | Missense Mutation (SNP) | VAF 9/74 reads (12%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.367); called by muse, mutect2, varscan2
- FETUB | c.372C>A p.N124K | Missense Mutation (SNP) | VAF 39/295 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- FGD5 | c.883G>T p.E295* | Nonsense Mutation (SNP) | VAF 75/157 reads (48%) | called by muse, mutect2, varscan2
- FGD5 | c.2412T>A p.F804L | Missense Mutation (SNP) | VAF 117/265 reads (44%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- FGG | c.974C>A p.P325H | Missense Mutation (SNP) | VAF 50/352 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); called by muse, mutect2, varscan2
- FLNC | c.6538C>A p.R2180S | Missense Mutation (SNP) | VAF 326/1104 reads (30%) | SIFT tolerated (0.74); PolyPhen benign (0.03); called by muse, mutect2, varscan2
- FOXRED1 | c.306G>T p.T102= | Splice Region (SNP) | VAF 240/701 reads (34%) | called by muse, mutect2, varscan2
- FRAS1 | c.888A>T p.E296D | Missense Mutation (SNP) | VAF 115/512 reads (22%) | SIFT tolerated (0.42); PolyPhen benign (0.035); called by muse, mutect2, varscan2
- GABRA1 | c.303G>T p.R101S | Missense Mutation (SNP) | VAF 90/494 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- GATA6 | c.20G>T p.G7V | Missense Mutation (SNP) | VAF 177/669 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.159); called by muse, mutect2, varscan2
- GCA | c.412A>T p.T138S | Missense Mutation (SNP) | VAF 73/411 reads (18%) | SIFT tolerated (0.16); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- GCH1 | c.388G>T p.V130L | Missense Mutation (SNP) | VAF 64/375 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.661); called by muse, mutect2, varscan2
- GDF2 | c.337A>G p.S113G | Missense Mutation (SNP) | VAF 34/63 reads (54%) | SIFT tolerated (0.08); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- GFRA2 | c.205C>A p.R69S | Missense Mutation (SNP) | VAF 136/601 reads (23%) | SIFT tolerated (0.54); PolyPhen benign (0.109); called by muse, mutect2, varscan2
- GLT1D1 | c.470-2A>C p.X157_splice | Splice Site (SNP) | VAF 34/163 reads (21%) | called by muse, mutect2, varscan2
- GLYAT | c.529del p.H177Mfs*5 | Frame Shift Del (DEL) | VAF 46/158 reads (29%) | called by mutect2, pindel
- GMDS | c.450C>A p.F150L | Missense Mutation (SNP) | VAF 20/91 reads (22%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.317); called by muse, mutect2, varscan2
- GOLGA3 | c.175G>T p.D59Y | Missense Mutation (SNP) | VAF 17/93 reads (18%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.246); called by muse, mutect2, varscan2
- GOT2 | c.631G>T p.A211S | Missense Mutation (SNP) | VAF 67/352 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); called by muse, mutect2, varscan2
- GPD2 | c.388G>A p.D130N | Missense Mutation (SNP) | VAF 207/797 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.589); called by muse, mutect2, varscan2
- GPR137 | c.907G>T p.D303Y | Missense Mutation (SNP) | VAF 40/233 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- GPS1 | c.873C>G p.I291M | Missense Mutation (SNP) | VAF 128/486 reads (26%) | SIFT tolerated (0.33); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- GRIA4 | c.854G>T p.R285I | Missense Mutation (SNP) | VAF 47/352 reads (13%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.556); called by muse, mutect2, varscan2
- GRID2 | c.107C>G p.S36C | Missense Mutation (SNP) | VAF 52/246 reads (21%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.887); called by muse, mutect2, varscan2
- GRIPAP1 | c.422A>T p.Q141L | Missense Mutation (SNP) | VAF 59/132 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- GRK4 | c.600G>C p.E200D (on ENST00000398052 / NM_182982.3; = p.E168D on NM_005307.3) | Missense Mutation (SNP) | VAF 52/193 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.467); called by muse, mutect2, varscan2
- HCRTR2 | c.601G>T p.A201S | Missense Mutation (SNP) | VAF 178/670 reads (27%) | SIFT tolerated (0.57); PolyPhen benign (0.102); called by muse, mutect2, varscan2
- HIVEP3 | c.3259C>T p.Q1087* | Nonsense Mutation (SNP) | VAF 8/46 reads (17%) | called by muse, mutect2
- HNRNPU | c.712C>G p.L238V (on ENST00000283179; = p.L300V on NM_004501.3) | Missense Mutation (SNP) | VAF 34/521 reads (7%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); called by muse, mutect2
- HOXA13 | c.730C>T p.Q244* | Nonsense Mutation (SNP) | VAF 464/1371 reads (34%) | called by muse, mutect2, varscan2
- HSPG2 | c.2136G>T p.M712I | Missense Mutation (SNP) | VAF 291/840 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- HYDIN | c.14886del p.D4963Tfs*41 | Frame Shift Del (DEL) | VAF 17/69 reads (25%) | called by mutect2, pindel, varscan2
- IDH2 | c.930C>G p.N310K | Missense Mutation (SNP) | VAF 231/473 reads (49%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- IFIH1 | c.365A>T p.Q122L | Missense Mutation (SNP) | VAF 21/196 reads (11%) | SIFT tolerated (0.65); PolyPhen possibly damaging (0.555); called by muse, mutect2, varscan2
- IGFBPL1 | c.352G>C p.D118H | Missense Mutation (SNP) | VAF 23/168 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- IGHV1-46 | c.176C>A p.A59D | Missense Mutation (SNP) | VAF 188/1051 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.93); called by muse, mutect2, varscan2
- IGKV3OR2-268 | c.218C>T p.S73F | Missense Mutation (SNP) | VAF 114/819 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.168); called by muse, mutect2, varscan2
- IKBKB | c.1208C>T p.P403L | Missense Mutation (SNP) | VAF 85/561 reads (15%) | SIFT tolerated (0.31); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- IMPA2 | c.751+1G>T p.X251_splice | Splice Site (SNP) | VAF 78/247 reads (32%) | called by muse, mutect2, varscan2
- INPP5D | c.1849C>A p.H617N (on ENST00000445964 / NM_001017915.3; = p.H616N on NM_005541.5) | Missense Mutation (SNP) | VAF 72/653 reads (11%) | SIFT tolerated (0.19); PolyPhen benign (0.396); called by muse, mutect2, varscan2
- INSC | c.1183G>T p.A395S | Missense Mutation (SNP) | VAF 158/420 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- INSRR | c.1300A>T p.T434S | Missense Mutation (SNP) | VAF 397/769 reads (52%) | SIFT tolerated (0.26); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- INSYN2B | c.497T>A p.V166E | Missense Mutation (SNP) | VAF 43/371 reads (12%) | SIFT tolerated (0.27); PolyPhen benign (0.087); called by muse, mutect2, varscan2
- IRAG1 | c.2650G>T p.G884W | Missense Mutation (SNP) | VAF 256/897 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- IRGC | c.733C>A p.L245M | Missense Mutation (SNP) | VAF 39/109 reads (36%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- IRX6 | c.904G>A p.G302S | Missense Mutation (SNP) | VAF 82/282 reads (29%) | SIFT tolerated (0.51); PolyPhen benign (0.001); called by muse, varscan2
- ISLR2 | c.313G>T p.D105Y | Missense Mutation (SNP) | VAF 102/224 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ITGAX | c.990G>T p.K330N | Missense Mutation (SNP) | VAF 65/176 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.745); called by muse, mutect2, varscan2
- ITGB3 | c.616A>G p.M206V | Missense Mutation (SNP) | VAF 114/667 reads (17%) | SIFT tolerated (0.41); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ITGBL1 | c.128C>A p.S43Y | Missense Mutation (SNP) | VAF 45/79 reads (57%) | SIFT deleterious (0); PolyPhen possibly damaging (0.851); called by muse, mutect2
- ITIH6 | c.730G>A p.A244T | Missense Mutation (SNP) | VAF 193/434 reads (44%) | SIFT deleterious (0); PolyPhen benign (0.165); called by muse, mutect2, varscan2
- ITPR2 | c.821C>T p.S274F | Missense Mutation (SNP) | VAF 349/722 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- JAKMIP1 | c.2234G>T p.R745M | Missense Mutation (SNP) | VAF 97/525 reads (18%) | SIFT tolerated (0.05); PolyPhen benign (0); called by muse, varscan2
- JMJD6 | c.556A>G p.I186V | Missense Mutation (SNP) | VAF 48/431 reads (11%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.509); called by muse, mutect2, varscan2
- JPH2 | c.504C>A p.S168R | Missense Mutation (SNP) | VAF 220/438 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- JPH4 | c.286G>A p.G96S | Missense Mutation (SNP) | VAF 35/231 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- KARS1 | c.1789G>T p.V597F | Missense Mutation (SNP) | VAF 77/386 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.655); called by muse, mutect2, varscan2
- KCNA4 | c.124G>T p.A42S | Missense Mutation (SNP) | VAF 72/214 reads (34%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.995); called by muse, varscan2
- KCNAB2 | c.967G>C p.G323R | Missense Mutation (SNP) | VAF 23/102 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- KCNE3 | c.228C>G p.I76M | Missense Mutation (SNP) | VAF 51/222 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.614); called by muse, mutect2, varscan2
- KCNG1 | c.526T>A p.F176I | Missense Mutation (SNP) | VAF 307/746 reads (41%) | SIFT tolerated (0.17); PolyPhen benign (0.028); called by muse, mutect2, varscan2
- KCNH7 | c.2347T>C p.Y783H | Missense Mutation (SNP) | VAF 119/732 reads (16%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.952); called by muse, mutect2, varscan2
- KCNH8 | c.1324G>T p.A442S | Missense Mutation (SNP) | VAF 254/590 reads (43%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.951); called by muse, mutect2, varscan2
- KCNJ16 | c.832A>T p.I278F | Missense Mutation (SNP) | VAF 98/957 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); called by muse, mutect2
- KDM4C | c.2944G>T p.D982Y | Missense Mutation (SNP) | VAF 58/379 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); called by muse, mutect2, varscan2
- KIAA0100 | c.5275G>T p.E1759* | Nonsense Mutation (SNP) | VAF 91/565 reads (16%) | called by muse, mutect2, varscan2
- KIAA1109 | c.4088G>C p.G1363A | Missense Mutation (SNP) | VAF 50/322 reads (16%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- KIAA1109 | c.8584G>C p.E2862Q | Missense Mutation (SNP) | VAF 14/134 reads (10%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- KIAA1109 | c.14968G>T p.A4990S | Missense Mutation (SNP) | VAF 106/557 reads (19%) | SIFT tolerated (0.07); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- KIAA1217 | c.3007C>G p.P1003A | Missense Mutation (SNP) | VAF 163/512 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- KIAA1549 | c.792G>T p.R264S | Missense Mutation (SNP) | VAF 92/469 reads (20%) | SIFT tolerated (0.23); PolyPhen benign (0.086); called by muse, mutect2, varscan2
- KIF26B | c.146G>T p.R49L | Missense Mutation (SNP) | VAF 44/363 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.761); called by muse, mutect2, varscan2
- KIR2DL1 | c.800G>T p.W267L | Missense Mutation (SNP) | VAF 202/864 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.589); called by muse, mutect2
- KIR2DL3 | c.449G>A p.S150N | Missense Mutation (SNP) | VAF 42/444 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.96); called by muse, mutect2, varscan2
- KIR2DL4 | c.820A>T p.T274S (on ENST00000396284; = p.T235S on NM_001080770.2) | Missense Mutation (SNP) | VAF 116/825 reads (14%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.885); called by muse, mutect2, varscan2
- KLHL24 | c.160C>T p.Q54* | Nonsense Mutation (SNP) | VAF 108/531 reads (20%) | called by muse, mutect2, varscan2
- KLK1 | c.679G>C p.V227L | Missense Mutation (SNP) | VAF 62/251 reads (25%) | SIFT tolerated (0.1); PolyPhen benign (0.001); called by muse, varscan2
- KLK6 | c.551G>T p.G184V | Missense Mutation (SNP) | VAF 107/320 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- KMT2A | c.7777G>T p.V2593L | Missense Mutation (SNP) | VAF 143/421 reads (34%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- KPNA1 | c.460_463dup p.A155Dfs*30 | Frame Shift Ins (INS) | VAF 77/272 reads (28%) | called by mutect2, pindel, varscan2
- KPRP | c.604A>T p.N202Y | Missense Mutation (SNP) | VAF 143/2753 reads (5%) | SIFT deleterious (0.02); PolyPhen benign (0.362); called by muse, mutect2
- KREMEN2 | c.1339C>A p.L447M (on ENST00000303746 / NM_172229.3; = p.L420= on NM_024507.4) | Missense Mutation (SNP) | VAF 65/268 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.916); called by muse, mutect2, varscan2
- KRT14 | c.77G>C p.G26A | Missense Mutation (SNP) | VAF 133/359 reads (37%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.794); called by muse, mutect2, varscan2
- KRT6A | c.286G>T p.A96S | Missense Mutation (SNP) | VAF 132/956 reads (14%) | SIFT tolerated (0.29); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- KRTAP1-4 | c.143del p.G48Afs*9 | Frame Shift Del (DEL) | VAF 355/1132 reads (31%) | called by mutect2, pindel, varscan2
- KRTAP13-2 | c.471C>A p.C157* | Nonsense Mutation (SNP) | VAF 116/350 reads (33%) | called by muse, mutect2, varscan2
- KRTAP13-2 | c.316A>T p.S106C | Missense Mutation (SNP) | VAF 164/473 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- KRTAP4-12 | c.413C>A p.P138H | Missense Mutation (SNP) | VAF 322/1038 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.873); called by muse, mutect2, varscan2
- LAMC2 | c.650G>A p.G217D | Missense Mutation (SNP) | VAF 348/1125 reads (31%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- LDLRAD4 | c.109G>T p.D37Y | Missense Mutation (SNP) | VAF 108/490 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.97); called by muse, mutect2, varscan2
- LIMD1 | c.854C>T p.P285L | Missense Mutation (SNP) | VAF 150/319 reads (47%) | SIFT tolerated (0.06); PolyPhen benign (0); called by muse, mutect2, varscan2
- LMLN | c.313G>A p.E105K | Missense Mutation (SNP) | VAF 52/143 reads (36%) | SIFT tolerated (0.21); PolyPhen benign (0.158); called by muse, mutect2, varscan2
- LMTK2 | c.922T>C p.W308R | Missense Mutation (SNP) | VAF 118/475 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); called by muse, mutect2, varscan2
- LMTK3 | c.4189A>C p.T1397P | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.133); called by muse, varscan2
- LOXHD1 | c.5545G>T p.D1849Y (on ENST00000642948; = p.D1787Y on NM_144612.7) | Missense Mutation (SNP) | VAF 23/166 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, varscan2
- LRFN1 | c.665T>A p.L222Q | Missense Mutation (SNP) | VAF 145/466 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- LRP1B | c.10555G>C p.D3519H | Missense Mutation (SNP) | VAF 72/538 reads (13%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.947); called by muse, mutect2, varscan2
- LRP1B | c.7919C>A p.T2640N | Missense Mutation (SNP) | VAF 71/573 reads (12%) | SIFT tolerated (0.24); PolyPhen benign (0.037); called by muse, varscan2
- LRRC66 | c.148G>C p.G50R | Missense Mutation (SNP) | VAF 53/306 reads (17%) | SIFT tolerated (0.98); PolyPhen benign (0.106); called by muse, mutect2, varscan2
- LRRTM1 | c.56G>A p.G19E | Missense Mutation (SNP) | VAF 13/27 reads (48%) | SIFT tolerated (0.6); PolyPhen probably damaging (0.942); called by muse, mutect2, varscan2
- LSM8 | c.59G>T p.G20V | Missense Mutation (SNP) | VAF 118/341 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- LTBP1 | c.90C>G p.Y30* | Nonsense Mutation (SNP) | VAF 91/216 reads (42%) | called by muse, mutect2
- LVRN | c.287del p.L96Hfs*20 | Frame Shift Del (DEL) | VAF 81/295 reads (27%) | called by mutect2, pindel, varscan2
- MAEL | c.97G>C p.A33P | Missense Mutation (SNP) | VAF 49/334 reads (15%) | SIFT tolerated (0.12); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- MAGEA12 | c.910C>A p.L304M | Missense Mutation (SNP) | VAF 188/350 reads (54%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.943); called by mutect2, varscan2
- MAGEC2 | c.755T>A p.V252E | Missense Mutation (SNP) | VAF 66/477 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.826); called by muse, mutect2, varscan2
- MAP3K19 | c.1979C>T p.P660L | Missense Mutation (SNP) | VAF 108/295 reads (37%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.87); called by muse, mutect2, varscan2
- MAPK14 | c.514G>T p.A172S | Missense Mutation (SNP) | VAF 591/1430 reads (41%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- MAPK8IP3 | c.2947C>G p.H983D | Missense Mutation (SNP) | VAF 142/322 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- MAST4 | c.4711G>C p.E1571Q (on ENST00000403625 / NM_001164664.2; = p.E1382Q on NM_015183.3) | Missense Mutation (SNP) | VAF 92/602 reads (15%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.351); called by muse, mutect2, varscan2
- MATN4 | c.1082G>T p.R361L (on ENST00000372754; = p.R320L on NM_003833.4) | Missense Mutation (SNP) | VAF 73/628 reads (12%) | PolyPhen benign (0.031); called by muse, mutect2, varscan2
- MBLAC1 | c.368_400del p.L123_V133del | In Frame Del (DEL) | VAF 15/108 reads (14%) | called by mutect2, pindel
- MC5R | c.501G>T p.W167C | Missense Mutation (SNP) | VAF 137/613 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MCHR2 | c.445A>T p.K149* | Nonsense Mutation (SNP) | VAF 127/294 reads (43%) | called by muse, mutect2, varscan2
- MCTP1 | c.2510A>C p.N837T | Missense Mutation (SNP) | VAF 47/358 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.575); called by muse, mutect2, varscan2
- MDC1 | c.1297G>T p.E433* | Nonsense Mutation (SNP) | VAF 83/178 reads (47%) | called by muse, mutect2, varscan2
- MDC1 | c.721G>A p.A241T | Missense Mutation (SNP) | VAF 142/346 reads (41%) | SIFT tolerated (0.29); PolyPhen benign (0.01); called by muse, varscan2
- MED12L | c.5870A>T p.Q1957L | Missense Mutation (SNP) | VAF 199/1005 reads (20%) | SIFT tolerated, low confidence (0.06); PolyPhen probably damaging (0.973); called by muse, mutect2, varscan2
- MEGF8 | c.7924G>T p.D2642Y (on ENST00000251268 / NM_001271938.2; = p.D2575Y on NM_001410.3) | Missense Mutation (SNP) | VAF 136/394 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- MGAM | c.4954A>T p.S1652C | Missense Mutation (SNP) | VAF 385/1188 reads (32%) | SIFT deleterious (0.02); PolyPhen benign (0.082); called by muse, mutect2, varscan2
- MGAT5B | c.59G>A p.R20K | Missense Mutation (SNP) | VAF 160/515 reads (31%) | SIFT tolerated, low confidence (0.77); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- MLIP | c.743del p.P248Qfs*81 | Frame Shift Del (DEL) | VAF 52/301 reads (17%) | called by mutect2, pindel, varscan2
- MRPL37 | c.153G>T p.E51D | Missense Mutation (SNP) | VAF 175/457 reads (38%) | SIFT tolerated (0.08); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- MSL1 | c.535G>T p.G179W | Missense Mutation (SNP) | VAF 44/216 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- MTMR3 | c.2104G>T p.G702* | Nonsense Mutation (SNP) | VAF 160/377 reads (42%) | called by muse, mutect2, varscan2
- MTMR8 | c.1026G>T p.W342C | Missense Mutation (SNP) | VAF 116/615 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MTMR9 | c.884G>C p.W295S | Missense Mutation (SNP) | VAF 70/435 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.77); called by muse, mutect2, varscan2
- MUC12 | c.13399G>T p.G4467* (on ENST00000379442; = p.G4324* on NM_001164462.1) | Nonsense Mutation (SNP) | VAF 277/1322 reads (21%) | called by muse, mutect2, varscan2
- MUC16 | c.42055C>A p.Q14019K | Missense Mutation (SNP) | VAF 87/148 reads (59%) | SIFT tolerated, low confidence (0.38); PolyPhen possibly damaging (0.766); called by muse, mutect2, varscan2
- MUC16 | c.5863C>A p.P1955T | Missense Mutation (SNP) | VAF 115/238 reads (48%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- MUC5AC | c.1592C>A p.S531* | Nonsense Mutation (SNP) | VAF 28/133 reads (21%) | called by muse, mutect2, varscan2
- MUC5AC | c.16054C>A p.P5352T | Missense Mutation (SNP) | VAF 47/148 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MUC5B | c.2948C>A p.P983H | Missense Mutation (SNP) | VAF 43/214 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, varscan2
- MUC5B | c.3078C>A p.C1026* | Nonsense Mutation (SNP) | VAF 6/17 reads (35%) | called by muse, mutect2, varscan2
- MYH11 | c.380C>A p.P127H | Missense Mutation (SNP) | VAF 185/864 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- MYLK | c.2262G>C p.W754C | Missense Mutation (SNP) | VAF 276/775 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MYLK | c.1530G>A p.M510I | Missense Mutation (SNP) | VAF 75/367 reads (20%) | SIFT tolerated (0.18); PolyPhen benign (0); called by muse, mutect2, varscan2
- MYO3A | c.408G>T p.M136I | Missense Mutation (SNP) | VAF 112/486 reads (23%) | SIFT deleterious (0.05); PolyPhen benign (0.098); called by muse, mutect2, varscan2
- MYO5A | c.2425G>A p.A809T | Missense Mutation (SNP) | VAF 313/804 reads (39%) | SIFT tolerated (0.05); PolyPhen benign (0.445); called by muse, mutect2, varscan2
- MYO7B | c.382G>T p.G128C | Missense Mutation (SNP) | VAF 89/422 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MYT1 | c.932T>A p.V311E | Missense Mutation (SNP) | VAF 51/99 reads (52%) | SIFT tolerated (0.09); PolyPhen benign (0); called by muse, mutect2, varscan2
- NARS1 | c.43G>T p.D15Y | Missense Mutation (SNP) | VAF 61/415 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NAV3 | c.5419C>A p.L1807I (on ENST00000397909 / NM_001024383.2; = p.L1785I on NM_014903.6) | Missense Mutation (SNP) | VAF 170/639 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.725); called by muse, mutect2, varscan2
- NBEA | c.8568G>T p.L2856F | Missense Mutation (SNP) | VAF 96/246 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.558); called by muse, mutect2, varscan2
- NBEAL1 | c.6443C>A p.P2148Q | Missense Mutation (SNP) | VAF 47/426 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.907); called by muse, mutect2, varscan2
- NDST4 | c.2312T>A p.L771Q | Missense Mutation (SNP) | VAF 57/286 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- NECTIN1 | c.1523C>T p.S508F | Missense Mutation (SNP) | VAF 16/84 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- NELL2 | c.1090C>G p.Q364E | Missense Mutation (SNP) | VAF 125/508 reads (25%) | SIFT tolerated (0.2); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- NELL2 | c.661T>G p.C221G | Missense Mutation (SNP) | VAF 98/510 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.598); called by muse, varscan2
- NEU2 | c.229G>T p.A77S | Missense Mutation (SNP) | VAF 55/126 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- NKX2-4 | c.569G>T p.R190M | Missense Mutation (SNP) | VAF 121/449 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- NLN | c.450G>T p.Q150H | Missense Mutation (SNP) | VAF 65/178 reads (37%) | SIFT deleterious (0.02); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- NLRP12 | c.1572G>T p.M524I | Missense Mutation (SNP) | VAF 286/952 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.313); called by muse, mutect2, varscan2
- NLRP2 | c.2488T>A p.L830M | Missense Mutation (SNP) | VAF 386/1205 reads (32%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- NLRP4 | c.1981C>T p.Q661* | Nonsense Mutation (SNP) | VAF 108/332 reads (33%) | called by muse, mutect2, varscan2
- NME9 | c.693C>G p.I231M (on ENST00000333911 / NM_001349024.2; = p.I170M on NM_178130.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 129/573 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- NOBOX | c.1703del p.G568Afs*16 | Frame Shift Del (DEL) | VAF 73/345 reads (21%) | called by mutect2, pindel, varscan2
- NOP58 | c.1389G>T p.K463N | Missense Mutation (SNP) | VAF 75/226 reads (33%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- NOS1AP | c.1444G>T p.E482* | Nonsense Mutation (SNP) | VAF 30/288 reads (10%) | called by muse, mutect2, varscan2
- NOS3 | c.1922C>A p.A641D | Missense Mutation (SNP) | VAF 221/457 reads (48%) | SIFT deleterious (0.02); PolyPhen benign (0.359); called by muse, mutect2, varscan2
- NPAP1 | c.2368C>A p.H790N | Missense Mutation (SNP) | VAF 120/265 reads (45%) | SIFT tolerated, low confidence (0.79); PolyPhen benign (0.087); called by muse, mutect2, varscan2
- NPAP1 | c.2972C>A p.T991N | Missense Mutation (SNP) | VAF 99/268 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.763); called by muse, mutect2, varscan2
- NPAS3 | c.1873G>T p.G625C (on ENST00000356141 / NM_001164749.2; = p.G593C on NM_022123.3) | Missense Mutation (SNP) | VAF 109/626 reads (17%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.592); called by muse, mutect2, varscan2
- NPHP3 | c.2399C>G p.T800S | Missense Mutation (SNP) | VAF 78/493 reads (16%) | SIFT tolerated (0.78); PolyPhen benign (0); called by muse, mutect2, varscan2
- NPHS2 | c.949G>A p.A317T | Missense Mutation (SNP) | VAF 81/389 reads (21%) | SIFT tolerated (0.09); PolyPhen benign (0.093); called by muse, mutect2
- NPIPA8 | c.488A>T p.Q163L | Missense Mutation (SNP) | VAF 120/646 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.146); called by mutect2, varscan2
- NR4A2 | c.658G>T p.V220L | Missense Mutation (SNP) | VAF 16/79 reads (20%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- NRXN1 | c.1921G>T p.V641L | Missense Mutation (SNP) | VAF 61/164 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.898); called by muse, mutect2, varscan2
- NSMCE4A | c.151G>C p.E51Q | Missense Mutation (SNP) | VAF 131/236 reads (56%) | SIFT tolerated, low confidence (0.23); PolyPhen possibly damaging (0.514); called by muse, mutect2, varscan2
- NSUN7 | c.1168A>T p.N390Y | Missense Mutation (SNP) | VAF 73/263 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- NT5C3B | c.472G>A p.G158S | Missense Mutation (SNP) | VAF 19/151 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NUP205 | c.3559G>C p.D1187H | Missense Mutation (SNP) | VAF 254/670 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NXPH1 | c.762A>T p.K254N | Missense Mutation (SNP) | VAF 80/277 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- OBSCN | c.18326G>T p.R6109L | Missense Mutation (SNP) | VAF 101/294 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.86); called by muse, mutect2, varscan2
- OR1J4 | c.236C>A p.P79Q | Missense Mutation (SNP) | VAF 188/565 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- OR1J4 | c.374C>A p.A125D | Missense Mutation (SNP) | VAF 95/244 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- OR2B6 | c.46G>T p.G16C | Missense Mutation (SNP) | VAF 30/310 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2
- OR2G6 | c.191G>T p.S64I | Missense Mutation (SNP) | VAF 123/965 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.564); called by muse, mutect2, varscan2
- OR2L5 | c.67G>T p.G23C | Missense Mutation (SNP) | VAF 66/461 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- OR2L5 | c.905G>T p.R302L | Missense Mutation (SNP) | VAF 38/284 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.503); called by muse, mutect2, varscan2
- OR4A15 | c.602G>A p.G201E | Missense Mutation (SNP) | VAF 164/504 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.943); called by muse, mutect2, varscan2
- OR4B1 | c.576G>A p.M192I | Missense Mutation (SNP) | VAF 147/486 reads (30%) | SIFT tolerated (0.57); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- OR4C3 | c.383T>A p.L128Q | Missense Mutation (SNP) | VAF 43/196 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- OR4N2 | c.315C>G p.H105Q | Missense Mutation (SNP) | VAF 136/885 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- OR51F2 | c.682C>A p.L228I | Missense Mutation (SNP) | VAF 25/183 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.919); called by muse, mutect2, varscan2
- OR51S1 | c.679C>A p.L227M | Missense Mutation (SNP) | VAF 13/134 reads (10%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.715); called by muse, mutect2
- OR52N5 | c.839C>A p.P280H | Missense Mutation (SNP) | VAF 74/307 reads (24%) | SIFT tolerated (0.33); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- OR5B2 | c.820G>T p.V274L | Missense Mutation (SNP) | VAF 298/945 reads (32%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.687); called by muse, mutect2, varscan2
- OR5H6 | c.868G>C p.E290Q (on ENST00000642105; = p.E274Q on NM_001005479.2) | Missense Mutation (SNP) | VAF 111/417 reads (27%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.449); called by muse, mutect2, varscan2
- OR5T2 | c.334T>C p.Y112H | Missense Mutation (SNP) | VAF 16/98 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.968); called by muse, varscan2
- OR6C65 | c.800C>G p.A267G | Missense Mutation (SNP) | VAF 47/237 reads (20%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.204); called by muse, mutect2, varscan2
- OR6T1 | c.830T>A p.L277Q | Missense Mutation (SNP) | VAF 147/1065 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- OR7C1 | c.692C>T p.A231V | Missense Mutation (SNP) | VAF 102/268 reads (38%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.05); called by muse, mutect2, varscan2
- OR8K1 | c.757G>T p.V253L | Missense Mutation (SNP) | VAF 30/228 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.469); called by muse, mutect2, varscan2
- OTC | c.588dup p.G197Wfs*28 | Frame Shift Ins (INS) | VAF 404/1128 reads (36%) | called by mutect2, pindel, varscan2
- OTOGL | c.4145C>A p.P1382H (on ENST00000547103; = p.P1373H on NM_173591.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 51/287 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- OTUD1 | c.534G>T p.E178D | Missense Mutation (SNP) | VAF 65/169 reads (38%) | SIFT deleterious (0.04); PolyPhen benign (0.332); called by muse, mutect2, varscan2
- PACS2 | c.397G>T p.A133S | Missense Mutation (SNP) | VAF 37/142 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); called by muse, mutect2, varscan2
- PARP1 | c.1936G>T p.G646C | Missense Mutation (SNP) | VAF 45/264 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); called by muse, mutect2, varscan2
- PAX5 | c.476-2A>T p.X159_splice | Splice Site (SNP) | VAF 50/203 reads (25%) | called by muse, mutect2, varscan2
- PCDH15 | c.4895G>T p.G1632V (on ENST00000644397 / NM_001354429.2; = p.G1574V on NM_001142771.2) | Missense Mutation (SNP) | VAF 188/522 reads (36%) | SIFT tolerated, low confidence (0.07); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PCDH9 | c.1094G>T p.S365I | Missense Mutation (SNP) | VAF 144/260 reads (55%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.806); called by muse, mutect2, varscan2
- PCDHA2 | c.1841G>T p.G614V | Missense Mutation (SNP) | VAF 220/635 reads (35%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- PCDHA5 | c.2109_2110del p.I703Mfs*88 | Frame Shift Del (DEL) | VAF 96/713 reads (13%) | called by mutect2, pindel, varscan2
- PCDHAC1 | c.424C>T p.R142C | Missense Mutation (SNP) | VAF 198/532 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- PCDHB12 | c.1690C>G p.P564A | Missense Mutation (SNP) | VAF 228/1242 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PCDHB13 | c.1712C>A p.P571H | Missense Mutation (SNP) | VAF 135/902 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- PCDHB3 | c.1777G>T p.D593Y | Missense Mutation (SNP) | VAF 334/1043 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PCDHB5 | c.892G>T p.A298S | Missense Mutation (SNP) | VAF 87/211 reads (41%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.101); called by muse, mutect2, varscan2
- PCDHB5 | c.1312G>T p.V438F | Missense Mutation (SNP) | VAF 212/1133 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.939); called by muse, mutect2, varscan2
- PCDHB5 | c.1619T>A p.L540Q | Missense Mutation (SNP) | VAF 371/1088 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PCDHB6 | c.878A>T p.N293I | Missense Mutation (SNP) | VAF 79/402 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.888); called by muse, mutect2, varscan2
- PCDHGA4 | c.590C>A p.S197Y | Missense Mutation (SNP) | VAF 167/512 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.967); called by muse, mutect2, varscan2
- PCDHGA4 | c.1010del p.G337Vfs*2 | Frame Shift Del (DEL) | VAF 34/251 reads (14%) | called by mutect2, pindel, varscan2
- PDE6B | c.348C>A p.D116E | Missense Mutation (SNP) | VAF 38/67 reads (57%) | SIFT tolerated (0.32); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- PEAK1 | c.613C>T p.Q205* | Nonsense Mutation (SNP) | VAF 109/302 reads (36%) | called by muse, mutect2, varscan2
- PEG3 | c.3907G>T p.V1303F | Missense Mutation (SNP) | VAF 33/102 reads (32%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.791); called by muse, mutect2, varscan2
- PEG3 | c.2358A>T p.E786D | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT tolerated (0.34); PolyPhen benign (0); called by muse, mutect2, varscan2
- PER3 | c.595G>A p.A199T | Missense Mutation (SNP) | VAF 99/602 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.941); called by muse, mutect2, varscan2
- PGC | c.461A>T p.Q154L | Missense Mutation (SNP) | VAF 74/484 reads (15%) | SIFT tolerated (0.29); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- PHACTR4 | c.483G>C p.E161D (on ENST00000373839 / NM_001350159.2; = p.E171D on NM_023923.4) | Missense Mutation (SNP) | VAF 24/164 reads (15%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.978); called by muse, mutect2
- PHRF1 | c.3497C>G p.P1166R (on ENST00000264555 / NM_001286581.2; = p.P1165R on NM_020901.4) | Missense Mutation (SNP) | VAF 51/408 reads (13%) | SIFT tolerated (0.13); PolyPhen benign (0.344); called by muse, mutect2, varscan2
- PI16 | c.228G>A p.W76* | Nonsense Mutation (SNP) | VAF 42/377 reads (11%) | called by muse, mutect2, varscan2
- PI3 | c.314G>A p.C105Y | Missense Mutation (SNP) | VAF 210/535 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PIK3CG | c.889del p.L297Sfs*19 | Frame Shift Del (DEL) | VAF 243/696 reads (35%) | called by mutect2, pindel, varscan2
- PIK3R5 | c.2458G>T p.D820Y | Missense Mutation (SNP) | VAF 330/566 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- PITRM1 | c.1219C>T p.L407F | Missense Mutation (SNP) | VAF 80/518 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.543); called by muse, mutect2, varscan2
- PKD2 | c.2205G>C p.K735N | Missense Mutation (SNP) | VAF 141/733 reads (19%) | SIFT tolerated (0.1); PolyPhen benign (0.172); called by muse, mutect2, varscan2
- PLA2G4A | c.1567G>T p.A523S | Missense Mutation (SNP) | VAF 81/566 reads (14%) | SIFT tolerated (0.28); PolyPhen benign (0.055); called by muse, mutect2, varscan2
- PLCH2 | c.3006C>A p.S1002R | Missense Mutation (SNP) | VAF 22/110 reads (20%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.282); called by muse, mutect2, varscan2
- PLOD2 | c.2149T>G p.L717V | Missense Mutation (SNP) | VAF 74/428 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.829); called by muse, mutect2, varscan2
- PMFBP1 | c.1797+1G>A p.X599_splice (on ENST00000537465; = p.X594_splice on NM_031293.3) | Splice Site (SNP) | VAF 34/173 reads (20%) | called by muse, varscan2
763 further variants in this file (237 protein-altering or splice-affecting, 321 silent, 205 other) are not listed here.
